Somatic mutation profile of tumor specimen 5a007558-764c-463b-a788-fdbccb (aliquot 5a007558-764c-463b-a788-fdbccb_D6) from CPTAC case 05CO037, project CPTAC-2 (Colon — Adenomas and Adenocarcinomas). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IIA.
Specimen 5a007558-764c-463b-a788-fdbccb: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cbbeefb3-a1a0-48ef-9cab-b6a3e89226c5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 5fd542b5-33a6-4657-943b-2749e0 (Blood Derived Normal), aliquot 5fd542b5-33a6-4657-943b-2749e0_D1_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8c13e5b2-9ddc-445c-a60a-3323fcd90433

The open-access MAF lists 1,777 somatic variants for this specimen: 1,201 protein-altering or splice-affecting, 339 silent, 237 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 827, Silent 339, Frame Shift Del 157, Frame Shift Ins 138, Intron 138, Nonsense Mutation 41, 3'UTR 39, Splice Site 19, 5'UTR 18, RNA 18, Splice Region 15, 5'Flank 14.

Variants (750 of 1,777; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BCL10 | c.57+1G>A p.X19_splice | Splice Site (SNP) | VAF 81/255 reads (32%) | catalogued as rs606231305, CS1412381, COSV65353474; ClinVar: pathogenic; called by muse, mutect2, varscan2
- BRCA2 | c.9097del p.T3033Lfs*29 | Frame Shift Del (DEL) | VAF 44/210 reads (21%) | catalogued as rs397507419; ClinVar: not provided / pathogenic; called by mutect2, varscan2
- CEP164 | c.2689C>T p.R897* | Nonsense Mutation (SNP) | VAF 46/260 reads (18%) | catalogued as rs764893412; ClinVar: pathogenic; called by muse, varscan2
- CP | c.1948G>A p.G650R | Missense Mutation (SNP) | VAF 146/486 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs776936158, CM025426, COSV52829886; ClinVar: pathogenic / likely pathogenic; called by mutect2, varscan2
- FBXW7 | c.1178G>A p.R393Q (on ENST00000281708 / NM_001349798.2; = p.R313Q on NM_018315.5) | Missense Mutation (SNP) | VAF 13/77 reads (17%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen benign (0.129); catalogued as rs1390822119, COSV55892508, COSV55937382; called by muse, mutect2, varscan2
- GATA2 | c.599del p.G200Vfs*18 | Frame Shift Del (DEL) | VAF 115/432 reads (27%) | catalogued as rs768767517, CD141459, COSV62006544, COSV62006643; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- GRIN2B | c.99dup p.S34Qfs*25 | Frame Shift Ins (INS) | VAF 64/367 reads (17%) | catalogued as rs398122823; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- IQSEC2 | c.4419dup p.S1474Qfs*133 | Frame Shift Ins (INS) | VAF 13/28 reads (46%) | catalogued as rs1569290954; ClinVar: pathogenic; called by mutect2, varscan2
- KANSL1 | c.779del p.G260Vfs*19 | Frame Shift Del (DEL) | VAF 74/240 reads (31%) | catalogued as rs748018297; ClinVar: uncertain significance / pathogenic; called by mutect2, varscan2
- LDLRAP1 | c.603dup p.S202Lfs*19 | Frame Shift Ins (INS) | VAF 24/118 reads (20%) | catalogued as rs781585299; ClinVar: pathogenic; called by mutect2, varscan2
- NF1 | c.4076del p.P1359Lfs*19 (on ENST00000358273 / NM_001042492.3; = p.P1359Lfs*26 on NM_000267.3) | Frame Shift Del (DEL) | VAF 68/269 reads (25%) | catalogued as rs1135402852, COSV62223081; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- NPHS1 | c.3554dup p.S1186Vfs*10 | Frame Shift Ins (INS) | VAF 105/404 reads (26%) | catalogued as rs750714387; ClinVar: likely pathogenic; called by mutect2, varscan2
- PPM1D | c.1714C>T p.R572* | Nonsense Mutation (SNP) | VAF 29/145 reads (20%) | catalogued as rs765769406, COSV59954582; ClinVar: uncertain significance / pathogenic; called by muse, mutect2, varscan2
- PPP3CA | c.844G>A p.E282K | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); catalogued as rs1553923787, COSV59920640; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PXDN | c.2568dup p.C857Lfs*10 | Frame Shift Ins (INS) | VAF 53/244 reads (22%) | catalogued as rs558163499; ClinVar: pathogenic; called by mutect2, varscan2
- SF3B4 | c.1060dup p.R354Pfs*132 | Frame Shift Ins (INS) | VAF 20/90 reads (22%) | catalogued as rs782357237; ClinVar: pathogenic; called by mutect2, varscan2
- SUOX | c.363dup p.P122Afs*29 | Frame Shift Ins (INS) | VAF 64/242 reads (26%) | catalogued as rs1555198521; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- TAPBP | c.619C>T p.R207* | Nonsense Mutation (SNP) | VAF 75/243 reads (31%) | catalogued as rs767195857, COSV70456672; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCC9 | c.2746C>T p.R916W | Missense Mutation (SNP) | VAF 57/232 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); catalogued as rs533032970; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ABHD11 | c.296C>T p.T99M | Missense Mutation (SNP) | VAF 25/83 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.9); catalogued as rs781874515; called by muse, mutect2, varscan2
- ACAP1 | c.1508G>A p.R503Q | Missense Mutation (SNP) | VAF 19/131 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1196900372, COSV99342028; called by muse, mutect2, varscan2
- ACOXL | c.454T>C p.S152P | Missense Mutation (SNP) | VAF 48/186 reads (26%) | SIFT tolerated (0.05); PolyPhen benign (0.396); catalogued as rs1185901714; called by muse, mutect2, varscan2
- ACTL6B | c.695dup p.N233Kfs*17 | Frame Shift Ins (INS) | VAF 55/220 reads (25%) | catalogued as rs779550102; called by mutect2, varscan2
- ACVR2A | c.1310del p.K437Rfs*5 | Frame Shift Del (DEL) | VAF 36/76 reads (47%) | catalogued as rs764719749, COSV104385546; called by mutect2, varscan2
- ADAMTS13 | c.3650T>C p.I1217T | Missense Mutation (SNP) | VAF 176/610 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as rs200847393, CM084785; called by muse, varscan2
- ADAMTS6 | c.1553G>A p.R518H | Missense Mutation (SNP) | VAF 37/114 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.945); catalogued as rs1442947114, COSV66862199; called by muse, mutect2, varscan2
- ADAMTSL2 | c.1232G>C p.G411A | Missense Mutation (SNP) | VAF 46/190 reads (24%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as rs1354448523; called by muse, mutect2, varscan2
- ADCY10 | c.1421C>T p.A474V | Missense Mutation (SNP) | VAF 72/266 reads (27%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.646); catalogued as rs764010084, COSV63242283; called by muse, mutect2, varscan2
- ADGRA3 | c.3772T>C p.S1258P | Missense Mutation (SNP) | VAF 97/360 reads (27%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs967844609; called by muse, mutect2, varscan2
- ADGRB2 | c.3448G>A p.A1150T | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as rs1303406955; called by muse, mutect2, varscan2
- ADGRD1 | c.865A>C p.T289P | Missense Mutation (SNP) | VAF 25/106 reads (24%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV55457900, COSV55460987; called by muse, mutect2, varscan2
- AFDN | c.1198T>C p.Y400H | Missense Mutation (SNP) | VAF 62/227 reads (27%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.322); catalogued as rs1453922261; called by muse, mutect2, varscan2
- AGAP3 | c.2350G>A p.G784R (on ENST00000622464; = p.G820R on NM_031946.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 36/162 reads (22%) | SIFT tolerated (0.45); PolyPhen probably damaging (0.911); catalogued as rs1185964420; called by muse, mutect2, varscan2
- AGO2 | c.1806dup p.A603Rfs*71 | Frame Shift Ins (INS) | VAF 30/80 reads (38%) | catalogued as rs748399150; called by mutect2, varscan2
- AGRN | c.3388G>A p.A1130T | Missense Mutation (SNP) | VAF 108/410 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.726); catalogued as rs762884989; called by muse, varscan2
- AGXT | c.901C>T p.R301C | Missense Mutation (SNP) | VAF 43/183 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.029); catalogued as rs886055841; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AK9 | c.2097_2100del p.E700Kfs*12 | Frame Shift Del (DEL) | VAF 9/37 reads (24%) | catalogued as rs776656230; called by mutect2, pindel, varscan2
- AKAP13 | c.7375G>A p.V2459I (on ENST00000394518 / NM_007200.5; = p.V2463I on NM_006738.6) | Missense Mutation (SNP) | VAF 31/99 reads (31%) | SIFT tolerated (0.35); PolyPhen benign (0.011); catalogued as rs141334273; called by muse, mutect2, varscan2
- AKNA | c.1513C>T p.P505S | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.931); catalogued as COSV56311956, COSV56315408; called by muse, mutect2, varscan2
- AKR1C2 | c.827G>A p.R276H | Missense Mutation (SNP) | VAF 35/158 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.311); catalogued as rs1277254274; called by muse, mutect2, varscan2
- AKR1C3 | c.50C>A p.P17H | Missense Mutation (SNP) | VAF 54/195 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.7); catalogued as COSV101003096; called by muse, mutect2, varscan2
- ALDH1A2 | c.1513G>A p.E505K | Missense Mutation (SNP) | VAF 130/475 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99990997; called by muse, mutect2, varscan2
- ANK2 | c.5426C>T p.A1809V | Missense Mutation (SNP) | VAF 63/207 reads (30%) | SIFT tolerated, low confidence (0.89); PolyPhen benign (0); catalogued as rs531261130, COSV52148371; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ANK3 | c.6712A>G p.M2238V | Missense Mutation (SNP) | VAF 18/172 reads (10%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0); catalogued as rs781367135; called by muse, mutect2, varscan2
- ANKFY1 | c.2221G>A p.A741T (on ENST00000341657 / NM_001330063.2; = p.A742T on NM_016376.5) | Missense Mutation (SNP) | VAF 33/106 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.009); catalogued as rs751831487, COSV58915730, COSV58923231; called by muse, mutect2, varscan2
- ANKRD18A | c.844del p.R282Efs*11 | Frame Shift Del (DEL) | VAF 36/152 reads (24%) | catalogued as rs1563970981; called by mutect2, varscan2
- AP002495.1 | c.475C>T p.R159* (on ENST00000528511; = p.R90* on NM_001375848.1) | Nonsense Mutation (SNP) | VAF 34/156 reads (22%) | catalogued as rs781471264; called by muse, mutect2, varscan2
- AP3B2 | c.1966G>A p.V656M | Missense Mutation (SNP) | VAF 43/167 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as rs1175600444; called by muse, mutect2, varscan2
- APC2 | c.877C>T p.R293C | Missense Mutation (SNP) | VAF 27/128 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs768478428; called by muse, mutect2, varscan2
- APLNR | c.673G>A p.A225T | Missense Mutation (SNP) | VAF 69/235 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.955); catalogued as rs749277146, COSV57241999; called by muse, mutect2, varscan2
- ARAP3 | c.3197C>T p.T1066M | Missense Mutation (SNP) | VAF 47/203 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs367852994; called by muse, mutect2, varscan2
- ARFGEF3 | c.5405del p.G1802Afs*11 | Frame Shift Del (DEL) | VAF 80/350 reads (23%) | catalogued as COSV52449567; called by mutect2, pindel, varscan2
- ARHGEF17 | c.2890G>A p.A964T | Missense Mutation (SNP) | VAF 17/448 reads (4%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.013); catalogued as rs1298383300, COSV55234204; called by muse, mutect2
- ARHGEF2 | c.1412G>A p.R471H (on ENST00000361247 / NM_001162383.2; = p.R443H on NM_004723.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/448 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs867149295; called by muse, mutect2
- ARID4A | c.623A>G p.K208R | Missense Mutation (SNP) | VAF 25/91 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.259); catalogued as COSV100794183; called by muse, mutect2, varscan2
- ARMC3 | c.1176C>T p.N392= | Splice Region (SNP) | VAF 31/101 reads (31%) | catalogued as rs146878370; called by muse, mutect2, varscan2
- ARMCX5-GPRASP2 | c.50del p.K17Rfs*21 | Frame Shift Del (DEL) | VAF 11/58 reads (19%) | catalogued as rs1290336606; called by mutect2, pindel, varscan2
- ASGR2 | c.534dup p.V179Rfs*22 | Frame Shift Ins (INS) | VAF 60/229 reads (26%) | catalogued as rs1567762621; called by mutect2, varscan2
- ASL | c.603-6C>A | Splice Region (SNP) | VAF 94/366 reads (26%) | catalogued as rs747521107; called by muse, varscan2
- ATG2B | c.3120del p.K1040Nfs*2 | Frame Shift Del (DEL) | VAF 32/128 reads (25%) | catalogued as rs771531141; called by mutect2, varscan2
- ATP12A | c.342dup p.F115Vfs*64 | Frame Shift Ins (INS) | VAF 40/165 reads (24%) | catalogued as rs35191129; called by mutect2, varscan2
- ATP6V0A2 | c.130G>A p.V44I | Missense Mutation (SNP) | VAF 42/171 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.034); catalogued as rs754043585, CD093112, COSV57750859; called by muse, mutect2, varscan2
- ATP7B | c.3577G>A p.A1193T | Missense Mutation (SNP) | VAF 111/295 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.731); catalogued as rs769531525, CM061647, COSV54437118; called by muse, mutect2, varscan2
- ATP9B | c.2836C>T p.Q946* | Nonsense Mutation (SNP) | VAF 24/109 reads (22%) | catalogued as COSV100302605; called by muse, mutect2, varscan2
- ATXN2L | c.2477C>T p.T826M | Missense Mutation (SNP) | VAF 41/174 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.63); catalogued as rs373039080; called by muse, mutect2, varscan2
- ATXN2L | c.2997del p.Q1002Kfs*50 | Frame Shift Del (DEL) | VAF 15/68 reads (22%) | catalogued as rs1288664341; called by mutect2, varscan2
- B3GAT3 | c.700G>A p.G234S | Missense Mutation (SNP) | VAF 69/382 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.051); catalogued as rs777541373; called by muse, mutect2, varscan2
- BAHCC1 | c.7790G>A p.R2597H | Missense Mutation (SNP) | VAF 87/541 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs370135483; called by muse, mutect2, varscan2
- BCAM | c.293G>A p.R98H | Missense Mutation (SNP) | VAF 37/151 reads (25%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.972); catalogued as rs776003390, COSV104373265; called by muse, mutect2, varscan2
- BCL11A | c.1841C>T p.A614V (on ENST00000335712 / NM_001365609.1; = p.A648V on NM_018014.4) | Missense Mutation (SNP) | VAF 73/257 reads (28%) | SIFT tolerated (0.34); PolyPhen benign (0.043); catalogued as rs987223589, COSV100185115; called by muse, mutect2, varscan2
- BEND5 | c.592C>T p.R198C | Missense Mutation (SNP) | VAF 40/142 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.446); catalogued as rs201098567; called by muse, mutect2, varscan2
- BICD1 | c.2114C>T p.A705V | Missense Mutation (SNP) | VAF 21/66 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs201936676; called by muse, mutect2, varscan2
- BMPR2 | c.104C>T p.A35V | Missense Mutation (SNP) | VAF 17/82 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs770128128, COSV65808758; called by muse, mutect2, varscan2
- BMPR2 | c.1748del p.N583Tfs*44 | Frame Shift Del (DEL) | VAF 51/207 reads (25%) | catalogued as rs772920507, COSV65808737; called by mutect2, pindel, varscan2
- BRD4 | c.3445C>T p.R1149W | Missense Mutation (SNP) | VAF 20/89 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs779348570, COSV54590688; called by muse, mutect2, varscan2
- BRPF3 | c.2926C>A p.P976T | Missense Mutation (SNP) | VAF 18/117 reads (15%) | SIFT tolerated (0.27); PolyPhen benign (0.335); catalogued as COSV60206547; called by muse, mutect2, varscan2
- BRSK1 | c.614A>G p.E205G | Missense Mutation (SNP) | VAF 104/315 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV58666488; called by muse, mutect2, varscan2
- C12orf42 | c.1009del p.R337Afs*19 | Frame Shift Del (DEL) | VAF 29/177 reads (16%) | catalogued as rs771322722; called by mutect2, pindel, varscan2
- C1QTNF8 | c.340C>T p.R114C | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.953); catalogued as rs750003262; called by muse, mutect2, varscan2
- C1S | c.842del p.K281Rfs*39 | Frame Shift Del (DEL) | VAF 52/284 reads (18%) | catalogued as rs781818365; called by mutect2, varscan2
- C2orf73 | c.309del p.F103Lfs*17 | Frame Shift Del (DEL) | VAF 17/80 reads (21%) | catalogued as rs747496393; called by mutect2, pindel, varscan2
- C4orf19 | c.576G>T p.W192C | Missense Mutation (SNP) | VAF 97/332 reads (29%) | SIFT tolerated (0.15); PolyPhen benign (0.025); catalogued as COSV99448399; called by muse, mutect2, varscan2
- CAAP1 | c.571A>T p.I191F | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT deleterious (0.05); PolyPhen benign (0.165); catalogued as COSV61700397; called by muse, mutect2, varscan2
- CABP4 | c.538C>T p.R180C | Missense Mutation (SNP) | VAF 153/577 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1361811313; called by muse, mutect2, varscan2
- CACNA1E | c.6854G>A p.R2285Q (on ENST00000367573 / NM_001205293.3; = p.R2242Q on NM_000721.4) | Missense Mutation (SNP) | VAF 44/163 reads (27%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.815); catalogued as rs775338609; called by muse, mutect2, varscan2
- CACTIN | c.286C>T p.R96W | Missense Mutation (SNP) | VAF 96/366 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs1244603265; called by muse, mutect2, varscan2
- CAGE1 | c.2238del p.A747Pfs*9 (on ENST00000512086; = p.A611Pfs*9 on NM_205864.3) | Frame Shift Del (DEL) | VAF 29/124 reads (23%) | catalogued as COSV57081154; called by mutect2, pindel, varscan2
- CAMK1D | c.93C>T p.T31= | Splice Region (SNP) | VAF 28/121 reads (23%) | catalogued as rs776833536, COSV66609504; called by muse, mutect2, varscan2
- CAMTA2 | c.2597dup p.A867Cfs*7 | Frame Shift Ins (INS) | VAF 52/218 reads (24%) | catalogued as rs745547658; called by mutect2, varscan2
- CBX6 | c.571G>A p.G191R | Missense Mutation (SNP) | VAF 50/242 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.074); catalogued as rs1184992423, COSV53320403; called by muse, mutect2, varscan2
- CCAR2 | c.1249del p.R417Gfs*89 | Frame Shift Del (DEL) | VAF 16/123 reads (13%) | catalogued as rs756536005; called by mutect2, pindel, varscan2
- CCDC136 | c.3143del p.K1048Sfs*3 | Frame Shift Del (DEL) | VAF 57/190 reads (30%) | catalogued as rs761237807; called by mutect2, pindel, varscan2
- CCDC146 | c.1879C>T p.R627C | Missense Mutation (SNP) | VAF 48/189 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.168); catalogued as rs200460755; called by muse, mutect2, varscan2
- CCDC189 | c.661C>T p.R221W | Missense Mutation (SNP) | VAF 37/220 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs367827173; called by muse, mutect2, varscan2
- CCDC88A | c.133G>A p.G45R | Missense Mutation (SNP) | VAF 16/122 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55058062; called by muse, mutect2, varscan2
- CCDC88B | c.2450C>T p.A817V | Missense Mutation (SNP) | VAF 50/163 reads (31%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.994); catalogued as rs770315982; called by muse, mutect2, varscan2
- CCNA2 | c.116C>T p.A39V | Missense Mutation (SNP) | VAF 83/311 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs1309912079; called by muse, mutect2, varscan2
- CD46 | c.735del p.K245Nfs*53 | Frame Shift Del (DEL) | VAF 66/236 reads (28%) | catalogued as rs1343140692; called by mutect2, pindel, varscan2
- CDC42BPB | c.4708C>T p.R1570* | Nonsense Mutation (SNP) | VAF 70/281 reads (25%) | catalogued as rs1416279074, COSV63474703; called by muse, mutect2, varscan2
- CDH24 | c.2135del p.P712Rfs*129 | Frame Shift Del (DEL) | VAF 20/70 reads (29%) | catalogued as rs752398646; called by mutect2, varscan2
- CDH26 | c.1238C>T p.A413V | Missense Mutation (SNP) | VAF 49/168 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.871); catalogued as rs913011918; called by muse, mutect2, varscan2
- CDH9 | c.2153G>A p.R718Q | Missense Mutation (SNP) | VAF 71/245 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs535692550, COSV50266744; called by muse, mutect2, varscan2
- CDHR4 | c.1912del p.H638Tfs*12 | Frame Shift Del (DEL) | VAF 39/218 reads (18%) | catalogued as rs932849375; called by mutect2, pindel, varscan2
- CDK5RAP2 | c.1148T>C p.L383P | Missense Mutation (SNP) | VAF 40/243 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV100575247, COSV62578521; called by muse, mutect2, varscan2
- CDKL2 | c.222del p.K74Nfs*5 | Frame Shift Del (DEL) | VAF 18/68 reads (26%) | catalogued as rs753353408; called by mutect2, varscan2
- CDNF | c.391del p.T131Hfs*12 | Frame Shift Del (DEL) | VAF 11/60 reads (18%) | catalogued as COSV65806243; called by mutect2, pindel, varscan2
- CDRT1 | c.928G>A p.A310T | Missense Mutation (SNP) | VAF 37/147 reads (25%) | SIFT tolerated (0.46); PolyPhen benign (0.01); catalogued as rs1467185114; called by muse, mutect2, varscan2
- CDRT4 | c.166C>T p.R56C | Missense Mutation (SNP) | VAF 120/440 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.219); catalogued as rs1462090910; called by muse, mutect2, varscan2
- CEP135 | c.3343C>T p.R1115C | Missense Mutation (SNP) | VAF 21/78 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs779689049, COSV57260114; called by muse, mutect2, varscan2
- CEP170B | c.3715C>T p.R1239C (on ENST00000453495; = p.R1168C on NM_015005.3) | Missense Mutation (SNP) | VAF 36/123 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs777919599; called by muse, mutect2
- CFAP46 | c.3262G>A p.D1088N | Missense Mutation (SNP) | VAF 27/122 reads (22%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as rs749206037, COSV63955578; called by muse, mutect2, varscan2
- CHAF1A | c.2657G>A p.R886H | Missense Mutation (SNP) | VAF 22/93 reads (24%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.988); catalogued as rs778336745, COSV56671337; called by muse, mutect2, varscan2
- CHDH | c.454C>T p.R152C | Missense Mutation (SNP) | VAF 74/269 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.873); catalogued as rs1469534673, COSV100179845; called by muse, mutect2, varscan2
- CHFR | c.862G>A p.V288I (on ENST00000432561 / NM_001161345.1; = p.V247I on NM_018223.2) | Missense Mutation (SNP) | VAF 49/181 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0.051); catalogued as rs764757412; called by muse, mutect2, varscan2
- CHST2 | c.622del p.D208Tfs*13 | Frame Shift Del (DEL) | VAF 47/200 reads (24%) | catalogued as COSV100535884; called by mutect2, varscan2
- CILP2 | c.2897G>A p.R966H | Missense Mutation (SNP) | VAF 70/272 reads (26%) | SIFT tolerated (0.14); PolyPhen benign (0.238); catalogued as rs1344989823; called by muse, mutect2, varscan2
- CKMT1A | c.1018C>T p.R340C | Missense Mutation (SNP) | VAF 21/71 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs776795516, COSV63256663; called by muse, mutect2, varscan2
- CLCA4 | c.218dup p.K74Qfs*9 | Frame Shift Ins (INS) | VAF 26/100 reads (26%) | catalogued as rs745822656; called by mutect2, varscan2
- CLDN12 | c.11G>A p.R4Q | Missense Mutation (SNP) | VAF 40/160 reads (25%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.014); catalogued as rs200372770, COSV55306578; called by muse, mutect2, varscan2
- CLEC1B | c.398T>C p.M133T | Missense Mutation (SNP) | VAF 103/343 reads (30%) | SIFT tolerated (0.58); PolyPhen benign (0.003); catalogued as rs1457495892; called by muse, mutect2, varscan2
- CMYA5 | c.10639-1G>A p.X3547_splice | Splice Site (SNP) | VAF 31/91 reads (34%) | catalogued as rs1226598524, COSV101484148; called by muse, mutect2, varscan2
- CNOT4 | c.505G>A p.A169T | Missense Mutation (SNP) | VAF 22/95 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as rs371838377; called by muse, mutect2, varscan2
- CNTNAP5 | c.1318C>T p.L440F | Missense Mutation (SNP) | VAF 37/174 reads (21%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV101443891, COSV70500898; called by muse, mutect2, varscan2
- COG2 | c.1499C>T p.S500L | Missense Mutation (SNP) | VAF 9/152 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.089); catalogued as COSV64187359; called by muse, mutect2
- COL1A2 | c.2623C>T p.L875F | Missense Mutation (SNP) | VAF 33/271 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV51954633; called by muse, mutect2, varscan2
- COL6A6 | c.3929T>C p.V1310A | Missense Mutation (SNP) | VAF 28/102 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.049); catalogued as rs1171832751; called by muse, varscan2
- CORO6 | c.719G>T p.R240L | Missense Mutation (SNP) | VAF 47/160 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); catalogued as rs745449873, COSV61470644; called by muse, mutect2, varscan2
- CPXM2 | c.518G>C p.G173A | Missense Mutation (SNP) | VAF 21/82 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.897); catalogued as rs776975412; called by muse, mutect2, varscan2
- CRK | c.401C>T p.A134V | Missense Mutation (SNP) | VAF 48/200 reads (24%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as rs772107356, COSV56032406; called by muse, mutect2, varscan2
- CRYBG2 | c.1226G>T p.R409M | Missense Mutation (SNP) | VAF 59/227 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.953); catalogued as COSV57483749; called by muse, mutect2, varscan2
- CSMD3 | c.1723G>A p.V575I (on ENST00000297405 / NM_001363185.1; = p.V471I on NM_052900.3) | Missense Mutation (SNP) | VAF 48/217 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV52357456; called by muse, varscan2
- CSRNP2 | c.367C>T p.R123C | Missense Mutation (SNP) | VAF 34/104 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); catalogued as rs775325554, COSV57334012; called by muse, mutect2, varscan2
- CWF19L2 | c.314del p.N105Tfs*32 | Frame Shift Del (DEL) | VAF 16/40 reads (40%) | catalogued as rs1389859233; called by mutect2, pindel, varscan2
- CWH43 | c.1582G>A p.A528T | Missense Mutation (SNP) | VAF 63/229 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV56938376; called by muse, mutect2, varscan2
- CXCL5 | c.29G>A p.R10H | Missense Mutation (SNP) | VAF 68/274 reads (25%) | SIFT deleterious (0.05); PolyPhen benign (0.379); catalogued as rs775499405, COSV56018351; called by muse, varscan2
- CYP27B1 | c.1321dup p.H441Pfs*24 | Frame Shift Ins (INS) | VAF 43/286 reads (15%) | catalogued as rs1565810563; called by mutect2, pindel, varscan2
- CYP2D6 | c.1490G>A p.R497H | Missense Mutation (SNP) | VAF 30/110 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1440526469; called by muse, mutect2, varscan2
- CYP3A43 | c.647del p.L216Wfs*7 | Frame Shift Del (DEL) | VAF 28/96 reads (29%) | catalogued as rs779975576; called by mutect2, pindel, varscan2
- DAAM2 | c.2272C>T p.R758* | Nonsense Mutation (SNP) | VAF 37/146 reads (25%) | catalogued as rs1214902987; called by muse, mutect2, varscan2
- DAB2IP | c.3073dup p.H1025Pfs*4 (on ENST00000408936; = p.H997Pfs*4 on NM_032552.3) | Frame Shift Ins (INS) | VAF 26/126 reads (21%) | catalogued as rs751187768; called by mutect2, varscan2
- DCAF4L2 | c.952C>A p.L318I | Missense Mutation (SNP) | VAF 39/295 reads (13%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.998); catalogued as COSV60481702; called by muse, mutect2, varscan2
- DCAF5 | c.26dup p.S10Qfs*51 | Frame Shift Ins (INS) | VAF 20/92 reads (22%) | catalogued as rs1395418077; called by pindel, varscan2
- DCHS2 | c.1457del p.P486Qfs*34 | Frame Shift Del (DEL) | VAF 37/183 reads (20%) | catalogued as rs767409155; called by mutect2, pindel, varscan2
- DDOST | c.1258C>T p.R420C (on ENST00000415136; = p.R403C on NM_005216.5) | Missense Mutation (SNP) | VAF 45/148 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1215054051; called by muse, mutect2, varscan2
- DDX20 | c.1660G>A p.V554I | Missense Mutation (SNP) | VAF 33/153 reads (22%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs181968690; called by muse, mutect2, varscan2
- DDX27 | c.2072del p.K691Rfs*4 | Frame Shift Del (DEL) | VAF 39/103 reads (38%) | catalogued as rs766714372; called by mutect2, varscan2
- DDX58 | c.1934del p.N645Ifs*12 | Frame Shift Del (DEL) | VAF 25/81 reads (31%) | catalogued as rs1563960915; called by mutect2, pindel, varscan2
- DEFB108B | c.103T>C p.C35R | Missense Mutation (SNP) | VAF 34/132 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1285313710; called by muse, mutect2
- DENND4B | c.4441C>T p.P1481S | Missense Mutation (SNP) | VAF 41/205 reads (20%) | SIFT tolerated (0.44); PolyPhen benign (0.006); catalogued as rs752850099; called by muse, mutect2, varscan2
- DENND5A | c.1864C>T p.R622C | Missense Mutation (SNP) | VAF 43/201 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.302); catalogued as rs767513507, COSV60238222; called by muse, mutect2, varscan2
- DHRS4 | c.830G>A p.R277H | Missense Mutation (SNP) | VAF 38/161 reads (24%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.447); catalogued as rs762740127; called by muse, mutect2, varscan2
- DISP3 | c.1738G>A p.V580I | Missense Mutation (SNP) | VAF 32/124 reads (26%) | SIFT tolerated (0.77); PolyPhen benign (0.003); catalogued as rs768365990, COSV99610105; called by muse, mutect2, varscan2
- DNAI4 | c.89del p.K30Rfs*28 | Frame Shift Del (DEL) | VAF 36/165 reads (22%) | catalogued as rs774662919; called by mutect2, pindel, varscan2
- DOCK7 | c.3664A>C p.S1222R (on ENST00000635253 / NM_001367561.1; = p.S1191R on NM_033407.3) | Missense Mutation (SNP) | VAF 23/71 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.241); catalogued as COSV52015762; called by muse, mutect2, varscan2
- DOK1 | c.665G>A p.R222H | Missense Mutation (SNP) | VAF 33/295 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1367121845; called by muse, mutect2, varscan2
- DPAGT1 | c.698dup p.T234Hfs*116 | Frame Shift Ins (INS) | VAF 66/363 reads (18%) | catalogued as rs35482889; called by mutect2, varscan2
- DPP4 | c.1352C>T p.P451L | Missense Mutation (SNP) | VAF 21/109 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0.325); catalogued as rs1264451958; called by muse, mutect2, varscan2
- DPP8 | c.479G>A p.R160H (on ENST00000341861 / NM_001320875.2; = p.R144H on NM_017743.6) | Missense Mutation (SNP) | VAF 25/98 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs373358439, COSV55682381; called by muse, mutect2, varscan2
- DPYD | c.2121del p.F707Lfs*4 | Frame Shift Del (DEL) | VAF 88/405 reads (22%) | catalogued as rs1475611014; called by mutect2, pindel, varscan2
- DSEL | c.78G>A p.M26I | Missense Mutation (SNP) | VAF 35/227 reads (15%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0); catalogued as rs765642118, COSV100025883; called by muse, mutect2, varscan2
- DTX2 | c.1783G>A p.G595S | Missense Mutation (SNP) | VAF 130/443 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs779458207; called by muse, mutect2, varscan2
- DUOX1 | c.3373G>A p.A1125T | Missense Mutation (SNP) | VAF 135/497 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); catalogued as rs201511067, COSV100368107; called by muse, mutect2, varscan2
- DYNC1I2 | c.105del p.E36Kfs*34 | Frame Shift Del (DEL) | VAF 14/52 reads (27%) | catalogued as rs755197346; called by mutect2, varscan2
- DZIP1 | c.144dup p.S49Qfs*156 | Frame Shift Ins (INS) | VAF 19/101 reads (19%) | catalogued as rs747750483; called by mutect2, pindel, varscan2
- E2F6 | c.106C>T p.L36= | Splice Region (SNP) | VAF 32/154 reads (21%) | catalogued as rs1382517796; called by mutect2, varscan2
- EBF4 | c.925C>T p.P309S (on ENST00000609451; = p.P305S on NM_001110514.1) | Missense Mutation (SNP) | VAF 37/169 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs1302710650; called by muse, mutect2, varscan2
- EBLN2 | c.745G>A p.V249I | Missense Mutation (SNP) | VAF 44/154 reads (29%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.739); catalogued as rs545224554; called by muse, mutect2, varscan2
- EHD4 | c.884G>A p.R295H | Missense Mutation (SNP) | VAF 89/369 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1002148237, COSV55004924; called by muse, mutect2, varscan2
- EIF2B3 | c.895C>T p.R299C | Missense Mutation (SNP) | VAF 78/347 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); catalogued as rs368540656; called by muse, mutect2, varscan2
- ELOA | c.1394del p.N465Mfs*19 | Frame Shift Del (DEL) | VAF 38/80 reads (48%) | catalogued as rs766700925; called by mutect2, varscan2
- EMP2 | c.359G>A p.R120H | Missense Mutation (SNP) | VAF 27/110 reads (25%) | SIFT tolerated (0.34); PolyPhen benign (0.027); catalogued as rs370673124, COSV63995815; called by muse, mutect2, varscan2
- EPHB1 | c.2396G>A p.R799H | Missense Mutation (SNP) | VAF 90/342 reads (26%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.998); catalogued as rs533462328, COSV67662549; called by muse, mutect2, varscan2
- EQTN | c.77-3del | Splice Region (DEL) | VAF 22/86 reads (26%) | catalogued as rs768793415; called by mutect2, varscan2
- ERP44 | c.539G>A p.R180Q | Missense Mutation (SNP) | VAF 19/73 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.045); catalogued as rs371595032; called by muse, mutect2, varscan2
- ESRP1 | c.1535del p.N512Tfs*2 | Frame Shift Del (DEL) | VAF 36/157 reads (23%) | catalogued as rs775950025; called by mutect2, varscan2
- EVPLL | c.374C>T p.A125V | Missense Mutation (SNP) | VAF 44/233 reads (19%) | SIFT tolerated (0.27); PolyPhen benign (0.096); catalogued as rs1245670992; called by mutect2, varscan2
- EXOC2 | c.25dup p.L9Pfs*9 | Frame Shift Ins (INS) | VAF 31/115 reads (27%) | catalogued as rs748159069; called by mutect2, varscan2
- EXPH5 | c.2305T>C p.S769P | Missense Mutation (SNP) | VAF 42/165 reads (25%) | SIFT tolerated (0.23); PolyPhen benign (0.031); catalogued as rs780640842; called by muse, mutect2, varscan2
- FAF1 | c.857A>G p.H286R | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.622); catalogued as rs757689865; called by muse, mutect2, varscan2
- FAM102A | c.325G>A p.E109K | Missense Mutation (SNP) | VAF 34/108 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs752984958, COSV55949112; called by muse, mutect2, varscan2
- FAM172A | c.341A>G p.E114G | Missense Mutation (SNP) | VAF 8/97 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.506); catalogued as rs988336046; called by muse, mutect2
- FAM186B | c.1507C>T p.R503W | Missense Mutation (SNP) | VAF 32/115 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.037); catalogued as rs770748895; called by muse, mutect2, varscan2
- FAM214B | c.1002dup p.S335Qfs*19 | Frame Shift Ins (INS) | VAF 38/168 reads (23%) | catalogued as rs775865641; called by mutect2, varscan2
- FANCA | c.2593A>G p.I865V | Missense Mutation (SNP) | VAF 61/251 reads (24%) | SIFT tolerated (0.74); PolyPhen benign (0.001); catalogued as rs878853662; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FARSA | c.1066G>A p.V356I | Missense Mutation (SNP) | VAF 41/142 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1412069323, COSV58904057; called by muse, mutect2, varscan2
- FAT2 | c.9263C>T p.T3088M | Missense Mutation (SNP) | VAF 83/384 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs377443658; called by muse, mutect2, varscan2
- FBXO21 | c.432dup p.E145* | Frame Shift Ins (INS) | VAF 24/106 reads (23%) | catalogued as rs772635228; called by mutect2, varscan2
- FCGBP | c.2414G>A p.G805D | Missense Mutation (SNP) | VAF 56/206 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.268); catalogued as rs1193667150; called by muse, varscan2
- FCHO1 | c.527G>A p.R176Q | Missense Mutation (SNP) | VAF 50/180 reads (28%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.895); catalogued as rs748511310; called by muse, mutect2, varscan2
- FER1L6 | c.3323G>A p.G1108E | Missense Mutation (SNP) | VAF 38/152 reads (25%) | SIFT tolerated (0.94); PolyPhen benign (0); catalogued as rs201279972; called by muse, varscan2
- FERD3L | c.219C>A p.D73E | Missense Mutation (SNP) | VAF 75/266 reads (28%) | SIFT tolerated (0.99); PolyPhen benign (0); catalogued as COSV51764181; called by muse, mutect2, varscan2
- FGFR2 | c.181C>T p.R61C | Missense Mutation (SNP) | VAF 99/328 reads (30%) | SIFT tolerated (0.23); PolyPhen benign (0.05); catalogued as rs1354205157, COSV100337040; called by muse, mutect2, varscan2
- FHL2 | c.529C>T p.R177W | Missense Mutation (SNP) | VAF 43/167 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs763291334; called by muse, mutect2, varscan2
- FOXD4L5 | c.451G>A p.A151T | Missense Mutation (SNP) | VAF 38/196 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs1269607096; called by mutect2, varscan2
- FOXE1 | c.356G>C p.G119A | Missense Mutation (SNP) | VAF 64/223 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs776090929; called by muse, varscan2
- FOXG1 | c.688C>T p.R230C | Missense Mutation (SNP) | VAF 131/473 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57396963; called by muse, mutect2, varscan2
- FOXJ2 | c.917A>C p.Q306P | Missense Mutation (SNP) | VAF 29/140 reads (21%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs745407957, COSV99368130; called by muse, mutect2, varscan2
- FOXO3 | c.723del p.K242Rfs*117 | Frame Shift Del (DEL) | VAF 44/193 reads (23%) | catalogued as COSV59631234; called by mutect2, pindel, varscan2
- FOXP1 | c.995C>T p.A332V | Missense Mutation (SNP) | VAF 75/248 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.139); catalogued as rs971116457, COSV59558070; called by muse, mutect2, varscan2
- FRAS1 | c.8788G>A p.V2930M | Missense Mutation (SNP) | VAF 54/215 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.331); catalogued as rs752444155; called by muse, mutect2, varscan2
- FREM1 | c.5735G>A p.R1912Q | Missense Mutation (SNP) | VAF 29/115 reads (25%) | SIFT tolerated (0.96); PolyPhen benign (0); catalogued as rs576839770; called by muse, mutect2, varscan2
- FRMPD2 | c.677C>T p.P226L | Missense Mutation (SNP) | VAF 57/217 reads (26%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs201865478, COSV59719704; called by muse, mutect2, varscan2
- FUT10 | c.455C>T p.P152L | Missense Mutation (SNP) | VAF 34/244 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1249086832; called by muse, mutect2, varscan2
- FUT6 | c.35C>T p.S12L | Missense Mutation (SNP) | VAF 42/357 reads (12%) | SIFT tolerated (0.7); PolyPhen benign (0.003); catalogued as rs377238448; called by muse, mutect2, varscan2
- FZD3 | c.33G>A p.W11* | Nonsense Mutation (SNP) | VAF 27/82 reads (33%) | catalogued as COSV53536827; called by muse, mutect2, varscan2
- GAB1 | c.50dup p.E18Gfs*34 | Frame Shift Ins (INS) | VAF 36/154 reads (23%) | catalogued as rs755581817; called by mutect2, varscan2
- GAD2 | c.983T>C p.V328A | Missense Mutation (SNP) | VAF 19/104 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0.052); catalogued as rs766748892; called by muse, mutect2, varscan2
- GALNT17 | c.413G>A p.R138H | Missense Mutation (SNP) | VAF 19/71 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs367824274; called by muse, mutect2, varscan2
- GALNT18 | c.931C>A p.P311T | Missense Mutation (SNP) | VAF 98/352 reads (28%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV99926345; called by muse, mutect2, varscan2
- GASK1A | c.110G>A p.R37H | Missense Mutation (SNP) | VAF 67/253 reads (26%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs772364071, COSV56181841; called by muse, mutect2, varscan2
- GBE1 | c.2011del p.S671Lfs*36 | Frame Shift Del (DEL) | VAF 25/161 reads (16%) | catalogued as rs780374709; called by mutect2, varscan2
- GGTLC1 | c.449A>G p.D150G | Missense Mutation (SNP) | VAF 192/746 reads (26%) | SIFT tolerated (0.05); PolyPhen benign (0.179); catalogued as COSV99601032; called by muse, mutect2, varscan2
- GINS1 | c.221G>A p.R74H | Missense Mutation (SNP) | VAF 22/71 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV52465760; called by muse, mutect2, varscan2
- GLE1 | c.1939C>T p.L647F | Missense Mutation (SNP) | VAF 89/322 reads (28%) | SIFT tolerated (0.18); PolyPhen benign (0.186); catalogued as COSV59410147; called by muse, mutect2, varscan2
- GNPAT | c.634A>G p.T212A | Missense Mutation (SNP) | VAF 56/230 reads (24%) | SIFT tolerated (0.35); PolyPhen benign (0.101); catalogued as COSV64153444; called by muse, mutect2, varscan2
- GOLGA6L4 | c.350G>A p.R117H | Missense Mutation (SNP) | VAF 44/304 reads (14%) | SIFT tolerated (0.83); PolyPhen benign (0.014); catalogued as rs201557137; called by muse, mutect2, varscan2
- GPATCH8 | c.2065C>T p.R689C | Missense Mutation (SNP) | VAF 120/465 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs191226521, COSV59200178; called by muse, mutect2, varscan2
- GPR156 | c.2364dup p.L789Afs*20 | Frame Shift Ins (INS) | VAF 65/228 reads (29%) | catalogued as rs1479316119; called by mutect2, pindel, varscan2
- GPR20 | c.821C>T p.T274M | Missense Mutation (SNP) | VAF 89/303 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.376); catalogued as rs753556010, COSV66683908; called by muse, mutect2, varscan2
- GPR89A | c.442A>G p.S148G | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT tolerated (0.16); PolyPhen benign (0.356); catalogued as rs1553689728; called by mutect2, varscan2
- GPSM2 | c.1362del p.K454Nfs*43 | Frame Shift Del (DEL) | VAF 47/192 reads (24%) | catalogued as COSV51442513; called by mutect2, pindel, varscan2
- GRIK5 | c.1852C>T p.R618C | Missense Mutation (SNP) | VAF 52/180 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs750145451, COSV53476974, COSV53484373; called by muse, mutect2, varscan2
- H2BC18 | c.146T>C p.V49A | Missense Mutation (SNP) | VAF 103/401 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.999); catalogued as COSV58944377; called by muse, mutect2, varscan2
- HAP1 | c.1523+2T>C p.X508_splice (on ENST00000310778 / NM_001367460.1; = p.X456_splice on NM_177977.3 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 36/137 reads (26%) | catalogued as rs782509605; called by muse, mutect2, varscan2
- HDAC1 | c.883A>G p.M295V | Missense Mutation (SNP) | VAF 97/317 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.026); catalogued as COSV100269494; called by muse, mutect2, varscan2
- HDAC6 | c.2503C>T p.R835W | Missense Mutation (SNP) | VAF 43/68 reads (63%) | SIFT deleterious (0.03); PolyPhen benign (0.046); catalogued as rs782041149, COSV61931277; called by muse, mutect2, varscan2
- HECA | c.1004dup p.H336Tfs*25 | Frame Shift Ins (INS) | VAF 59/244 reads (24%) | catalogued as rs771658394; called by mutect2, varscan2
- HECTD3 | c.2119C>T p.R707W | Missense Mutation (SNP) | VAF 78/293 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs749722688; called by muse, mutect2, varscan2
- HECTD4 | c.13100dup p.D4368Rfs*44 | Frame Shift Ins (INS) | VAF 29/96 reads (30%) | catalogued as rs746492036; called by mutect2, varscan2
- HECW2 | c.4279C>T p.R1427C | Missense Mutation (SNP) | VAF 10/121 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53671221; called by muse, mutect2
- HJURP | c.1997G>A p.R666H | Missense Mutation (SNP) | VAF 35/124 reads (28%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs770730360, COSV100982636; called by muse, mutect2, varscan2
- HJURP | c.1289G>A p.R430H | Missense Mutation (SNP) | VAF 69/242 reads (29%) | SIFT tolerated (0.35); PolyPhen benign (0.007); catalogued as rs914831404; called by muse, mutect2, varscan2
- HMCN1 | c.5651A>G p.Q1884R | Missense Mutation (SNP) | VAF 66/202 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.329); catalogued as rs142871818; called by muse, mutect2, varscan2
- HMGN3 | c.76del p.R26Gfs*69 | Frame Shift Del (DEL) | VAF 25/132 reads (19%) | catalogued as COSV51513905, COSV51515635; called by mutect2, pindel, varscan2
- HNF4G | c.202C>T p.R68* (on ENST00000354370 / NM_001330561.2; = p.R115* on NM_004133.5) | Nonsense Mutation (SNP) | VAF 27/126 reads (21%) | catalogued as rs1427781416, COSV62966913; called by muse, mutect2, varscan2
- HOXB3 | c.211G>A p.G71S | Missense Mutation (SNP) | VAF 77/262 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.267); catalogued as rs772166761; called by muse, mutect2, varscan2
- HPRT1 | c.270T>A p.D90E | Missense Mutation (SNP) | VAF 68/129 reads (53%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as CD075444; called by muse, mutect2, varscan2
- HSPG2 | c.9745C>T p.R3249C | Missense Mutation (SNP) | VAF 123/521 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1316494531, COSV65933138; called by muse, mutect2
- IFT140 | c.1381G>A p.G461R | Missense Mutation (SNP) | VAF 66/212 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs146049665; called by muse, mutect2, varscan2
- IFT81 | c.1358A>G p.K453R | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV54362066; called by muse, mutect2, varscan2
- IGDCC4 | c.959G>A p.R320H | Missense Mutation (SNP) | VAF 51/195 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV61537743; called by muse, mutect2, varscan2
- IGHA1 | c.701C>T p.P234L | Missense Mutation (SNP) | VAF 108/691 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs759216050; called by muse, mutect2, varscan2
- IKZF4 | c.1714G>A p.E572K | Missense Mutation (SNP) | VAF 39/163 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.009); catalogued as COSV56266841; called by muse, mutect2, varscan2
- ILF3 | c.839C>T p.A280V | Missense Mutation (SNP) | VAF 42/185 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.297); catalogued as COSV51554083; called by muse, varscan2
- INTS1 | c.2185G>A p.A729T | Missense Mutation (SNP) | VAF 26/112 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs756570358, COSV67177505; called by muse, mutect2, varscan2
- ITGA2 | c.2881G>A p.V961M | Missense Mutation (SNP) | VAF 25/170 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.092); catalogued as rs143880458; called by muse, mutect2, varscan2
- ITGB8 | c.27dup p.T10Yfs*34 | Frame Shift Ins (INS) | VAF 22/102 reads (22%) | catalogued as rs760028800; called by mutect2, varscan2
- ITIH4 | c.754A>G p.I252V | Missense Mutation (SNP) | VAF 25/88 reads (28%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.591); catalogued as rs754348864; called by muse, mutect2, varscan2
- ITIH5 | c.592G>A p.A198T | Missense Mutation (SNP) | VAF 28/154 reads (18%) | SIFT tolerated (0.99); PolyPhen benign (0.013); catalogued as rs1247790056, COSV56906234; called by muse, mutect2, varscan2
- ITPR1 | c.58G>T p.E20* | Nonsense Mutation (SNP) | VAF 29/99 reads (29%) | catalogued as COSV100231880; called by muse, mutect2, varscan2
- ITPR3 | c.3335C>T p.S1112L | Missense Mutation (SNP) | VAF 32/232 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs769275266; called by muse, mutect2, varscan2
- JAKMIP1 | c.556G>A p.A186T | Missense Mutation (SNP) | VAF 92/326 reads (28%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs377118462; called by muse, mutect2, varscan2
- JPH4 | c.172G>A p.G58R | Missense Mutation (SNP) | VAF 76/224 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1403374739; called by muse, mutect2, varscan2
- KANSL1 | c.3194G>A p.R1065H (on ENST00000574590 / NM_001193465.2; = p.R1066H on NM_015443.4) | Missense Mutation (SNP) | VAF 66/281 reads (23%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as rs368475798, COSV52237183; called by muse, mutect2, varscan2
- KBTBD3 | c.1067G>A p.R356Q | Missense Mutation (SNP) | VAF 98/393 reads (25%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.863); catalogued as rs889600137, COSV73241300; called by muse, mutect2, varscan2
- KCNA1 | c.47del p.P16Rfs*25 | Frame Shift Del (DEL) | VAF 108/368 reads (29%) | catalogued as rs1565432905, COSV66837931; called by mutect2, varscan2
- KCNH6 | c.1154G>A p.R385H | Missense Mutation (SNP) | VAF 64/217 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs771497152; called by muse, mutect2, varscan2
- KCNK9 | c.391C>T p.R131C | Missense Mutation (SNP) | VAF 125/501 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57278639; called by muse, mutect2, varscan2
- KCNN3 | c.335dup p.S113Ffs*22 | Frame Shift Ins (INS) | VAF 50/241 reads (21%) | catalogued as rs753256170; called by mutect2, varscan2
- KCNN4 | c.508C>T p.R170C | Missense Mutation (SNP) | VAF 114/433 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); catalogued as COSV53455959; called by muse, mutect2, varscan2
- KCP | c.301C>T p.R101C | Missense Mutation (SNP) | VAF 40/160 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs774922609, COSV52823569; called by muse, mutect2, varscan2
- KDM4B | c.1835G>A p.R612H | Missense Mutation (SNP) | VAF 60/256 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV50241714; called by muse, mutect2, varscan2
- KIAA1217 | c.4078G>A p.V1360M | Missense Mutation (SNP) | VAF 66/243 reads (27%) | SIFT tolerated (0.28); PolyPhen benign (0.009); catalogued as rs374899929; called by muse, mutect2, varscan2
- KIAA1328 | c.1442C>T p.A481V | Missense Mutation (SNP) | VAF 19/72 reads (26%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as rs201629444, COSV54447646; called by muse, mutect2, varscan2
- KIF16B | c.662G>A p.S221N | Missense Mutation (SNP) | VAF 34/141 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs985175559; called by muse, mutect2, varscan2
- KIF26B | c.1637G>A p.G546D | Missense Mutation (SNP) | VAF 30/102 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100831454; called by muse, mutect2, varscan2
- KISS1R | c.43dup p.A15Gfs*179 | Frame Shift Ins (INS) | VAF 52/204 reads (25%) | catalogued as rs1226311997; called by pindel, varscan2
- KLHDC9 | c.387del p.A130Pfs*37 | Frame Shift Del (DEL) | VAF 51/206 reads (25%) | catalogued as rs761803466; called by mutect2, varscan2
- KLHL33 | c.707G>A p.R236Q | Missense Mutation (SNP) | VAF 60/231 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.36); catalogued as rs909833622; called by muse, mutect2, varscan2
- KMT2C | c.5836C>T p.P1946S | Missense Mutation (SNP) | VAF 76/275 reads (28%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.852); catalogued as rs1563290134, COSV51519773; called by muse, mutect2, varscan2
- KRT9 | c.250A>G p.S84G | Missense Mutation (SNP) | VAF 28/145 reads (19%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0); catalogued as rs563000405, COSV55852742; called by muse, mutect2, varscan2
- LAMA4 | c.3514G>A p.D1172N (on ENST00000230538 / NM_001105206.3; = p.D1165N on NM_002290.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 157/574 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV57895653, COSV57905490; called by muse, mutect2, varscan2
- LAMB2 | c.2435G>A p.R812H | Missense Mutation (SNP) | VAF 18/328 reads (5%) | SIFT tolerated (0.16); PolyPhen benign (0.346); catalogued as rs886058674, COSV100025772; ClinVar: uncertain significance; called by muse, mutect2
- LARP1 | c.434del p.P145Qfs*10 | Frame Shift Del (DEL) | VAF 6/39 reads (15%) | catalogued as COSV60428595; called by pindel, varscan2
- LCE2C | c.245A>G p.H82R | Missense Mutation (SNP) | VAF 55/212 reads (26%) | SIFT tolerated, low confidence (0.23); PolyPhen possibly damaging (0.55); catalogued as rs757417978; called by muse, mutect2, varscan2
- LCK | c.156A>T p.E52D | Missense Mutation (SNP) | VAF 47/209 reads (22%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs373458731; called by muse, mutect2, varscan2
- LCMT2 | c.1249C>T p.R417C | Missense Mutation (SNP) | VAF 72/270 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs1466855643, COSV99980290; called by muse, varscan2
- LHPP | c.661G>A p.G221S | Missense Mutation (SNP) | VAF 30/109 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.966); catalogued as rs538187592; called by muse, mutect2, varscan2
- LPA | c.209C>T p.A70V | Missense Mutation (SNP) | VAF 55/195 reads (28%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.921); catalogued as rs544895795, COSV60306719; called by muse, mutect2, varscan2
- LPCAT1 | c.164C>T p.P55L | Missense Mutation (SNP) | VAF 64/246 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1440315285; called by muse, mutect2, varscan2
- LPIN1 | c.2200C>T p.R734W | Missense Mutation (SNP) | VAF 63/246 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs200324087; called by muse, mutect2, varscan2
- LPIN3 | c.335dup p.L113Sfs*15 | Frame Shift Ins (INS) | VAF 72/193 reads (37%) | catalogued as rs756955559; called by mutect2, varscan2
- LRCH4 | c.1732C>T p.R578W | Missense Mutation (SNP) | VAF 40/191 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs367912586; called by muse, mutect2, varscan2
- LRGUK | c.1298G>A p.R433H | Missense Mutation (SNP) | VAF 14/133 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs751565610, COSV53633960; called by muse, mutect2, varscan2
- LRP1B | c.13101del p.H4368Tfs*4 | Frame Shift Del (DEL) | VAF 30/106 reads (28%) | catalogued as rs751694974; called by mutect2, varscan2
- LRRC19 | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 11/40 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs888501624; called by muse, mutect2, varscan2
- LRRC70 | c.1634dup p.L545Ffs*9 | Frame Shift Ins (INS) | VAF 32/134 reads (24%) | catalogued as rs754228010; called by mutect2, varscan2
- LRRC8A | c.1207C>T p.R403W | Missense Mutation (SNP) | VAF 108/408 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV99396740; called by muse, mutect2, varscan2
- LRSAM1 | c.1162G>A p.A388T | Missense Mutation (SNP) | VAF 114/424 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs138715791; called by muse, mutect2, varscan2
- LTBP4 | c.1712C>T p.A571V (on ENST00000308370 / NM_001042544.1; = p.A534V on NM_003573.2) | Missense Mutation (SNP) | VAF 40/211 reads (19%) | SIFT tolerated (0.64); PolyPhen benign (0.003); catalogued as rs778489116; called by muse, mutect2, varscan2
- LTF | c.1085C>T p.A362V | Missense Mutation (SNP) | VAF 41/132 reads (31%) | SIFT tolerated (0.26); PolyPhen benign (0.027); catalogued as rs774481814; called by mutect2, varscan2
- LTO1 | c.614G>A p.R205H | Missense Mutation (SNP) | VAF 24/111 reads (22%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.049); catalogued as rs1270452510; called by muse, mutect2, varscan2
- LUC7L3 | c.1165dup p.S389Kfs*2 | Frame Shift Ins (INS) | VAF 26/115 reads (23%) | catalogued as rs1229438198; called by mutect2, varscan2
- LVRN | c.925G>A p.A309T | Missense Mutation (SNP) | VAF 41/159 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs377469881; called by muse, mutect2, varscan2
- LY6G6C | c.28T>A p.S10T | Missense Mutation (SNP) | VAF 27/136 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.345); catalogued as COSV101009659; called by muse, mutect2, varscan2
- LZTR1 | c.800G>A p.R267H | Missense Mutation (SNP) | VAF 45/231 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); catalogued as rs754364555, COSV53144890; called by muse, mutect2, varscan2
- MACF1 | c.2582G>A p.R861H | Missense Mutation (SNP) | VAF 23/100 reads (23%) | catalogued as rs373088168; called by muse, mutect2, varscan2
- MAP3K2 | c.323G>A p.R108H | Missense Mutation (SNP) | VAF 20/76 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.381); catalogued as rs753590225, COSV61295051; called by muse, mutect2, varscan2
- MAP3K9 | c.2540G>A p.R847H (on ENST00000554752 / NM_001284230.1; = p.R861H on NM_033141.4) | Missense Mutation (SNP) | VAF 73/255 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs775490417; called by muse, mutect2, varscan2
- MAP3K9 | c.1490G>A p.R497Q | Missense Mutation (SNP) | VAF 64/252 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.043); catalogued as rs56196343; called by muse, mutect2, varscan2
- MAP9 | c.1490dup p.N497Kfs*6 | Frame Shift Ins (INS) | VAF 12/30 reads (40%) | catalogued as rs778055136; called by mutect2, varscan2
- MARVELD2 | c.1578del p.E527Nfs*6 | Frame Shift Del (DEL) | VAF 44/168 reads (26%) | catalogued as COSV57780447; called by mutect2, varscan2
- MBD1 | c.1054C>T p.R352C (on ENST00000269468 / NM_001323950.1; = p.R329C on NM_015845.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 177/586 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.747); catalogued as rs1424033110, COSV53999035; called by muse, mutect2, varscan2
- MC4R | c.867A>G p.I289M | Missense Mutation (SNP) | VAF 123/429 reads (29%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.985); catalogued as COSV55353149; called by muse, mutect2, varscan2
- MCAM | c.335G>A p.R112H | Missense Mutation (SNP) | VAF 117/467 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.993); catalogued as rs747992430, COSV50686572, COSV99877619; called by muse, mutect2, varscan2
- MCAT | c.986C>T p.T329M | Missense Mutation (SNP) | VAF 130/506 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs751275986, COSV51793275, COSV51793943; called by muse, varscan2
- MCAT | c.907G>A p.A303T | Missense Mutation (SNP) | VAF 97/336 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.015); catalogued as rs765693023, COSV51791790; called by muse, varscan2
- MCPH1 | c.1552G>A p.A518T | Missense Mutation (SNP) | VAF 45/183 reads (25%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as rs748320867, COSV60919166; called by muse, mutect2, varscan2
- MCTP2 | c.1525G>A p.G509S | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs759600196, COSV59151154; called by muse, mutect2, varscan2
- MDN1 | c.12163C>T p.R4055C | Missense Mutation (SNP) | VAF 26/126 reads (21%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs373502418; called by muse, mutect2, varscan2
- MDN1 | c.5966del p.K1989Rfs*65 | Frame Shift Del (DEL) | VAF 6/40 reads (15%) | catalogued as rs750092100; called by mutect2, varscan2
- MESD | c.632dup p.K212Efs*19 | Frame Shift Ins (INS) | VAF 40/242 reads (17%) | catalogued as rs745891632; called by mutect2, varscan2
- MFSD12 | c.773C>T p.A258V | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT tolerated (0.35); PolyPhen benign (0.033); catalogued as rs1329491009; called by muse, mutect2, varscan2
- MGAT5B | c.1627del p.L543Wfs*71 (on ENST00000569840 / NM_001199172.2; = p.L541Wfs*71 on NM_144677.3) | Frame Shift Del (DEL) | VAF 25/101 reads (25%) | catalogued as rs778939334; called by mutect2, pindel, varscan2
- MMP14 | c.409G>A p.E137K | Missense Mutation (SNP) | VAF 36/182 reads (20%) | SIFT tolerated (0.24); PolyPhen benign (0.094); catalogued as rs764791818; called by muse, mutect2, varscan2
- MN1 | c.3407G>A p.R1136H | Missense Mutation (SNP) | VAF 84/297 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV56556844; called by muse, mutect2, varscan2
- MOXD1 | c.53C>T p.A18V | Missense Mutation (SNP) | VAF 31/161 reads (19%) | SIFT tolerated (0.34); PolyPhen benign (0.108); catalogued as rs1287975086; called by muse, mutect2, varscan2
- MPC2 | c.353A>G p.N118S | Missense Mutation (SNP) | VAF 21/83 reads (25%) | SIFT tolerated (0.21); PolyPhen benign (0.089); catalogued as COSV54796805; called by muse, mutect2, varscan2
- MRC1 | c.3299T>C p.V1100A | Missense Mutation (SNP) | VAF 92/336 reads (27%) | SIFT tolerated (0.59); PolyPhen benign (0.031); catalogued as rs1350352907; called by muse, mutect2, varscan2
- MRE11 | c.1180G>T p.D394Y | Missense Mutation (SNP) | VAF 52/217 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60580003; called by muse, mutect2, varscan2
- MTF1 | c.190G>A p.D64N | Missense Mutation (SNP) | VAF 60/265 reads (23%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.578); catalogued as rs774017828; called by muse, mutect2, varscan2
- MTIF2 | c.1974dup p.F659Ifs*2 | Frame Shift Ins (INS) | VAF 22/74 reads (30%) | catalogued as rs770359991; called by mutect2, varscan2
- MTX1 | c.872G>A p.R291H | Missense Mutation (SNP) | VAF 101/348 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.171); catalogued as rs143655609; called by muse, mutect2, varscan2
- MTX2 | c.637G>A p.A213T | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs866538702, COSV99980787; called by muse, mutect2, varscan2
- MUC16 | c.30233G>A p.G10078D | Missense Mutation (SNP) | VAF 60/217 reads (28%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.01); catalogued as rs779653452; called by muse, mutect2, varscan2
- MUC5B | c.17276C>T p.A5759V | Missense Mutation (SNP) | VAF 90/370 reads (24%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.012); catalogued as rs760860799; called by mutect2, varscan2
- MXRA8 | c.901del p.R301Gfs*107 | Frame Shift Del (DEL) | VAF 48/173 reads (28%) | catalogued as rs764857791; called by mutect2, pindel, varscan2
- MYBPH | c.704C>T p.S235L | Missense Mutation (SNP) | VAF 30/226 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.329); catalogued as rs372799255; called by muse, mutect2, varscan2
- MYH6 | c.2519C>T p.P840L | Missense Mutation (SNP) | VAF 120/521 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62454745; called by muse, mutect2, varscan2
- MYO19 | c.1883C>T p.A628V | Missense Mutation (SNP) | VAF 47/284 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.721); catalogued as rs1028003487; called by muse, mutect2, varscan2
- MYO5B | c.1489A>G p.I497V | Missense Mutation (SNP) | VAF 145/587 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.821); catalogued as rs751000651; called by muse, mutect2, varscan2
- MYO9B | c.5327G>A p.R1776Q | Missense Mutation (SNP) | VAF 87/328 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.261); catalogued as rs764590855; called by muse, mutect2, varscan2
- NAA25 | c.1985dup p.S663Qfs*11 | Frame Shift Ins (INS) | VAF 16/48 reads (33%) | catalogued as rs1324340510; called by mutect2, varscan2
- NAALAD2 | c.1686dup p.Q563Tfs*14 | Frame Shift Ins (INS) | VAF 39/188 reads (21%) | catalogued as rs1221515108; called by mutect2, varscan2
- NAGK | c.805G>A p.V269M | Missense Mutation (SNP) | VAF 38/160 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.86); catalogued as rs750765230; called by muse, mutect2, varscan2
- NBEA | c.3905G>A p.R1302Q | Missense Mutation (SNP) | VAF 33/135 reads (24%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0); catalogued as rs746740466, COSV100077428, COSV59791280; called by muse, mutect2, varscan2
- NBN | c.1735A>G p.K579E | Missense Mutation (SNP) | VAF 74/272 reads (27%) | SIFT tolerated (0.5); PolyPhen benign (0.003); catalogued as rs993110145; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NCAPD3 | c.535A>G p.R179G | Missense Mutation (SNP) | VAF 28/104 reads (27%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.797); catalogued as COSV101596381; called by muse, mutect2, varscan2
- NCOR1 | c.4514-5del | Splice Region (DEL) | VAF 34/142 reads (24%) | catalogued as rs1476264466; called by mutect2, varscan2
- NDST2 | c.566T>C p.L189P | Missense Mutation (SNP) | VAF 60/218 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55212973, COSV55213427; called by muse, mutect2, varscan2
- NDUFB1 | c.25C>T p.R9W | Missense Mutation (SNP) | VAF 39/151 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs763642344; called by muse, varscan2
- NEB | c.13727C>T p.T4576M | Missense Mutation (SNP) | VAF 35/122 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs371689870; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NECTIN4 | c.1403C>T p.A468V | Missense Mutation (SNP) | VAF 141/552 reads (26%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs762666261; called by muse, mutect2, varscan2
- NEDD4 | c.1982G>A p.R661H (on ENST00000508342 / NM_001284338.1; = p.R242H on NM_006154.4) | Missense Mutation (SNP) | VAF 32/116 reads (28%) | SIFT tolerated (0.82); PolyPhen benign (0.003); catalogued as rs369378356; called by muse, mutect2, varscan2
- NEK5 | c.767G>T p.R256M | Missense Mutation (SNP) | VAF 66/170 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV62878788, COSV62879727; called by muse, mutect2, varscan2
- NHSL2 | c.1912G>A p.V638I (on ENST00000510661; = p.V1004I on NM_001013627.2) | Missense Mutation (SNP) | VAF 46/113 reads (41%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.503); catalogued as rs937347346, COSV65453336; called by muse, mutect2, varscan2
- NIN | c.5964G>A p.M1988I (on ENST00000382041 / NM_182946.1; = p.M1275I on NM_016350.4) | Missense Mutation (SNP) | VAF 50/245 reads (20%) | SIFT tolerated (0.14); PolyPhen benign (0.022); catalogued as rs767905943; called by muse, mutect2, varscan2
- NINJ1 | c.181G>A p.A61T | Missense Mutation (SNP) | VAF 69/260 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as rs144669023; called by muse, mutect2, varscan2
- NLRP14 | c.643dup p.Y215Lfs*8 | Frame Shift Ins (INS) | VAF 64/284 reads (23%) | catalogued as rs767663966; called by mutect2, pindel, varscan2
- NLRP9 | c.1190C>T p.A397V | Missense Mutation (SNP) | VAF 30/204 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.04); catalogued as COSV60463380; called by muse, mutect2, varscan2
- NOL4L | c.396dup p.Y133Lfs*18 | Frame Shift Ins (INS) | VAF 36/148 reads (24%) | catalogued as rs751187638; called by mutect2, varscan2
- NOSTRIN | c.572del p.N191Tfs*9 (on ENST00000317647 / NM_001039724.4; = p.N113Tfs*9 on NM_052946.3) | Frame Shift Del (DEL) | VAF 39/150 reads (26%) | catalogued as rs1282346576; called by mutect2, varscan2
- NOTCH1 | c.1205C>T p.S402L | Missense Mutation (SNP) | VAF 36/638 reads (6%) | SIFT tolerated (0.11); PolyPhen benign (0.013); catalogued as rs1037236860, COSV53036803, COSV53081435; ClinVar: uncertain significance; called by muse, mutect2
- NOTCH2 | c.1502A>G p.N501S | Missense Mutation (SNP) | VAF 17/441 reads (4%) | SIFT tolerated (1); PolyPhen benign (0.191); catalogued as COSV56686855; called by muse, mutect2
- NPC2 | c.441C>T p.I147= | Splice Region (SNP) | VAF 50/196 reads (26%) | catalogued as rs769285370, COSV53143891; called by muse, mutect2, varscan2
- NPIPB11 | c.2902C>T p.R968C | Missense Mutation (SNP) | VAF 36/412 reads (9%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.129); catalogued as rs1306597369; called by muse, varscan2
- NPRL2 | c.1027C>T p.R343W | Missense Mutation (SNP) | VAF 86/330 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs765232395; called by muse, mutect2, varscan2
- NPRL2 | c.422C>T p.A141V | Missense Mutation (SNP) | VAF 47/264 reads (18%) | SIFT tolerated (0.24); PolyPhen benign (0.02); catalogued as rs774253805; called by muse, mutect2, varscan2
- NRXN1 | c.3608C>T p.S1203F | Missense Mutation (SNP) | VAF 96/406 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.421); catalogued as rs756194214; called by muse, varscan2
- NUFIP2 | c.670del p.R224Gfs*16 | Frame Shift Del (DEL) | VAF 37/258 reads (14%) | catalogued as rs772197760; called by mutect2, pindel, varscan2
- NUP214 | c.681del p.V228Sfs*29 | Frame Shift Del (DEL) | VAF 38/140 reads (27%) | catalogued as rs771913112, COSV63912486; called by mutect2, varscan2
- NUP54 | c.1247C>T p.T416M | Missense Mutation (SNP) | VAF 23/126 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.695); catalogued as rs754816608; called by muse, mutect2, varscan2
- NUTM2A | c.863A>G p.Q288R | Missense Mutation (SNP) | VAF 112/496 reads (23%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.983); catalogued as COSV67741809; called by muse, varscan2
- NXF1 | c.663T>G p.D221E | Missense Mutation (SNP) | VAF 68/279 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.236); catalogued as rs1300710679; called by muse, mutect2, varscan2
- NYNRIN | c.3292A>G p.M1098V | Missense Mutation (SNP) | VAF 76/238 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1002469716; called by muse, mutect2, varscan2
- OBSCN | c.26C>T p.A9V | Missense Mutation (SNP) | VAF 38/128 reads (30%) | SIFT tolerated (0.22); PolyPhen benign (0.208); catalogued as rs989786157; called by muse, mutect2
- OCA2 | c.1808del p.N603Ifs*25 | Frame Shift Del (DEL) | VAF 30/178 reads (17%) | catalogued as rs1476192724; called by mutect2, pindel, varscan2
- OPLAH | c.259G>A p.A87T | Missense Mutation (SNP) | VAF 67/275 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1018525295; called by muse, mutect2, varscan2
- OR11H6 | c.370del p.S124Hfs*31 | Frame Shift Del (DEL) | VAF 80/436 reads (18%) | catalogued as rs762454146; called by mutect2, pindel, varscan2
- OR13C2 | c.39dup p.L14Sfs*11 | Frame Shift Ins (INS) | VAF 27/106 reads (25%) | catalogued as rs1312362242; called by mutect2, pindel, varscan2
- OR2J3 | c.215T>C p.L72P | Missense Mutation (SNP) | VAF 64/213 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1007345397; called by muse, varscan2
- OR4C6 | c.286C>A p.L96I | Missense Mutation (SNP) | VAF 68/336 reads (20%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.057); catalogued as COSV58606296; called by muse, varscan2
- OR51I2 | c.460A>G p.I154V | Missense Mutation (SNP) | VAF 114/396 reads (29%) | SIFT tolerated (0.73); PolyPhen benign (0.019); catalogued as rs1231089485; called by muse, mutect2, varscan2
- OR5A1 | c.181C>T p.P61S | Missense Mutation (SNP) | VAF 137/537 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV57377821; called by muse, mutect2, varscan2
- OR5D18 | c.295G>A p.V99I | Missense Mutation (SNP) | VAF 60/363 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs566365669, COSV61736850, COSV61737947; called by muse, mutect2, varscan2
- OR8I2 | c.139A>G p.T47A | Missense Mutation (SNP) | VAF 34/141 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as rs1289420731; called by muse, mutect2, varscan2
- OSBP2 | c.1852C>T p.R618C | Missense Mutation (SNP) | VAF 66/222 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs779479198; called by muse, varscan2
- OSBPL1A | c.1115G>A p.R372Q | Missense Mutation (SNP) | VAF 26/101 reads (26%) | SIFT tolerated (0.49); PolyPhen benign (0.045); catalogued as rs747432259; called by muse, mutect2, varscan2
- OSBPL7 | c.2398G>A p.V800I | Missense Mutation (SNP) | VAF 77/237 reads (32%) | SIFT tolerated (0.12); PolyPhen benign (0.025); catalogued as rs755376628, COSV50107934; called by muse, mutect2, varscan2
- OTOG | c.8128G>A p.V2710M | Missense Mutation (SNP) | VAF 77/291 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.387); catalogued as rs1001847378; called by muse, mutect2, varscan2
- OTOGL | c.2185G>A p.G729S (on ENST00000547103; = p.G720S on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 61/237 reads (26%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.973); catalogued as rs766979240, COSV72006611; called by muse, mutect2, varscan2
- OTOP1 | c.215C>T p.A72V | Missense Mutation (SNP) | VAF 24/130 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.229); catalogued as rs568093695, COSV99587842; called by muse, varscan2
- OVOL3 | c.388G>A p.G130S (on ENST00000585332; = p.G106S on NM_001302757.1) | Missense Mutation (SNP) | VAF 95/384 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs892513316; called by muse, mutect2, varscan2
- P3H1 | c.8T>C p.V3A | Missense Mutation (SNP) | VAF 54/278 reads (19%) | SIFT tolerated, low confidence (0.71); PolyPhen benign (0); catalogued as COSV52536389; called by mutect2, varscan2
- PAK6 | c.1434G>A p.W478* | Nonsense Mutation (SNP) | VAF 51/202 reads (25%) | catalogued as rs775883119; called by muse, mutect2, varscan2
- PALLD | c.3364C>T p.R1122* (on ENST00000505667 / NM_001166108.2; = p.R1105* on NM_016081.4) | Nonsense Mutation (SNP) | VAF 72/281 reads (26%) | catalogued as rs145720372; called by muse, mutect2, varscan2
- PANK1 | c.1199dup p.P401Afs*5 (on ENST00000307534 / NM_148977.2; = p.P176Afs*5 on NM_138316.4) | Frame Shift Ins (INS) | VAF 51/206 reads (25%) | catalogued as rs1564621823; called by mutect2, varscan2
- PARP12 | c.841C>T p.R281W | Missense Mutation (SNP) | VAF 46/155 reads (30%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs191980703, COSV54933651; called by muse, mutect2, varscan2
- PAX8 | c.157G>A p.V53I | Missense Mutation (SNP) | VAF 69/295 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs1336411411; called by muse, mutect2, varscan2
- PBRM1 | c.834A>T p.K278N | Missense Mutation (SNP) | VAF 23/84 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.493); catalogued as rs1560714275, COSV56284877; called by muse, mutect2, varscan2
- PBX4 | c.403C>T p.R135* | Nonsense Mutation (SNP) | VAF 57/208 reads (27%) | catalogued as rs764835727; called by muse, mutect2, varscan2
- PCARE | c.1837C>T p.R613* | Nonsense Mutation (SNP) | VAF 153/580 reads (26%) | catalogued as rs772325487, COSV100527437; called by muse, varscan2
- PCDH10 | c.2215C>T p.R739C | Missense Mutation (SNP) | VAF 78/258 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV52099108, COSV99993103; called by muse, varscan2
- PCDHGB7 | c.1742C>T p.A581V | Missense Mutation (SNP) | VAF 94/400 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.904); catalogued as rs753678898; called by muse, mutect2, varscan2
- PDE8B | c.361C>T p.R121C | Missense Mutation (SNP) | VAF 40/202 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as rs576161372, COSV53742939; called by muse, mutect2, varscan2
- PER1 | c.1138del p.L380Cfs*73 | Frame Shift Del (DEL) | VAF 44/172 reads (26%) | catalogued as rs1196410930; called by mutect2, pindel, varscan2
- PGAM5 | c.498C>T p.G166= | Splice Region (SNP) | VAF 48/214 reads (22%) | catalogued as rs779878029; called by muse, mutect2, varscan2
- PGS1 | c.734G>A p.R245H | Missense Mutation (SNP) | VAF 40/222 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs749520109; called by muse, mutect2, varscan2
- PHTF2 | c.1709del p.L570Cfs*4 (on ENST00000248550 / NM_001366089.1; = p.L532Cfs*4 on NM_020432.5 and 4 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 33/129 reads (26%) | catalogued as rs775426168; called by mutect2, varscan2
- PIK3C2B | c.860G>A p.R287H | Missense Mutation (SNP) | VAF 41/165 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs745376966, COSV65804261; called by muse, mutect2, varscan2
- PIP5K1A | c.887dup p.L296Ffs*4 (on ENST00000368888 / NM_001135638.2; = p.L283Ffs*4 on NM_003557.3) | Frame Shift Ins (INS) | VAF 74/292 reads (25%) | catalogued as rs756244757; called by mutect2, varscan2
- PKDREJ | c.1376A>G p.H459R | Missense Mutation (SNP) | VAF 51/206 reads (25%) | SIFT tolerated (0.51); PolyPhen benign (0.007); catalogued as COSV53546383; called by muse, mutect2, varscan2
- PLA2G4F | c.2497G>A p.A833T | Missense Mutation (SNP) | VAF 61/301 reads (20%) | SIFT tolerated (0.16); PolyPhen benign (0.397); catalogued as rs775787567, COSV51829753; called by muse, mutect2, varscan2
- PLCG1 | c.1787C>T p.T596M | Missense Mutation (SNP) | VAF 26/80 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1413308040, COSV54823341; called by muse, mutect2, varscan2
- PLEKHA4 | c.241G>A p.G81S | Missense Mutation (SNP) | VAF 72/201 reads (36%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.958); catalogued as rs770347579, COSV54362488; called by muse, mutect2, varscan2
- PLEKHF1 | c.739G>A p.D247N | Missense Mutation (SNP) | VAF 51/197 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.105); catalogued as rs750018420; called by muse, mutect2, varscan2
- PLEKHG2 | c.2512G>A p.A838T | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.984); catalogued as COSV99218165; called by muse, mutect2, varscan2
- PLEKHG2 | c.3964dup p.Q1322Pfs*19 | Frame Shift Ins (INS) | VAF 34/116 reads (29%) | catalogued as rs551236586; called by mutect2, varscan2
- PLEKHG3 | c.3419C>T p.P1140L (on ENST00000394691; = p.P1196L on NM_001308147.2) | Missense Mutation (SNP) | VAF 43/184 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.162); catalogued as rs770955432; called by muse, mutect2, varscan2
- PLEKHG6 | c.704G>T p.R235L | Missense Mutation (SNP) | VAF 59/194 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.655); catalogued as rs767451979; called by muse, mutect2, varscan2
- PLK3 | c.775C>T p.P259S | Missense Mutation (SNP) | VAF 75/530 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59501226; called by muse, mutect2, varscan2
- PMP22 | c.253T>C p.C85R | Missense Mutation (SNP) | VAF 135/517 reads (26%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.522); catalogued as CD982894; called by muse, mutect2, varscan2
- PODNL1 | c.676C>T p.R226* | Nonsense Mutation (SNP) | VAF 47/170 reads (28%) | catalogued as rs774196210; called by muse, mutect2, varscan2
- POLD1 | c.2959dup p.X987_splice | Splice Site (INS) | VAF 55/206 reads (27%) | catalogued as rs756872503; ClinVar: uncertain significance; called by mutect2, varscan2
- POMK | c.43dup p.R15Pfs*85 | Frame Shift Ins (INS) | VAF 33/168 reads (20%) | catalogued as rs749980792; called by mutect2, varscan2
- PPP1R10 | c.2815dup p.L939Pfs*62 | Frame Shift Ins (INS) | VAF 48/160 reads (30%) | catalogued as rs750124216; called by mutect2, varscan2
- PPP1R10 | c.2084dup p.P696Sfs*10 | Frame Shift Ins (INS) | VAF 22/110 reads (20%) | catalogued as rs760405117; called by mutect2, varscan2
- PPP1R18 | c.1550dup p.Y518Lfs*22 | Frame Shift Ins (INS) | VAF 22/90 reads (24%) | catalogued as rs1278252175; called by mutect2, pindel, varscan2
- PPP1R26 | c.3290dup p.R1098Qfs*60 | Frame Shift Ins (INS) | VAF 22/77 reads (29%) | catalogued as rs764146060; called by mutect2, varscan2
- PPP6R1 | c.1364G>A p.C455Y | Missense Mutation (SNP) | VAF 57/345 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.001); catalogued as rs1411507870; called by muse, mutect2, varscan2
- PRDM13 | c.179C>T p.S60L | Missense Mutation (SNP) | VAF 32/110 reads (29%) | SIFT tolerated (0.05); PolyPhen benign (0.39); catalogued as rs1295183516, COSV65030077; called by muse, mutect2, varscan2
- PRKAR1A | c.1054C>T p.R352* | Nonsense Mutation (SNP) | VAF 102/373 reads (27%) | catalogued as COSV56835672; called by muse, mutect2, varscan2
- PRKCE | c.1091G>A p.R364Q | Missense Mutation (SNP) | VAF 66/242 reads (27%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as rs769788896; called by muse, mutect2, varscan2
- PROSER1 | c.1099T>C p.S367P | Missense Mutation (SNP) | VAF 64/165 reads (39%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs1220412545; called by muse, mutect2, varscan2
- PRPF40B | c.1102C>T p.R368W (on ENST00000380281; = p.R362W on NM_012272.3) | Missense Mutation (SNP) | VAF 29/132 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs367823648; called by muse, mutect2, varscan2
- PRPF4B | c.2567G>A p.R856H | Missense Mutation (SNP) | VAF 43/173 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV61784421; called by muse, mutect2, varscan2
- PRRX2 | c.373C>T p.R125C | Missense Mutation (SNP) | VAF 37/144 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs546912518; called by muse, mutect2, varscan2
- PRTG | c.3167dup p.Q1057Pfs*9 | Frame Shift Ins (INS) | VAF 23/100 reads (23%) | catalogued as rs768325902; called by mutect2, varscan2
- PSME1 | c.440A>G p.N147S | Missense Mutation (SNP) | VAF 103/356 reads (29%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.985); catalogued as rs1206819114; called by muse, mutect2, varscan2
- PTCHD4 | c.1474A>G p.I492V | Missense Mutation (SNP) | VAF 62/254 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as rs748141587; called by muse, mutect2, varscan2
- PTGDR2 | c.727C>T p.R243C | Missense Mutation (SNP) | VAF 24/49 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs749242968, COSV57126481; called by muse, mutect2, varscan2
- PTGDR2 | c.427C>T p.R143C | Missense Mutation (SNP) | VAF 126/534 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs777277288; called by muse, varscan2
- PTX4 | c.1191del p.G398Efs*57 (on ENST00000447419 / NM_001328608.2; = p.G393Efs*57 on NM_001013658.1) | Frame Shift Del (DEL) | VAF 69/349 reads (20%) | catalogued as rs772722517, COSV99560265; called by mutect2, pindel, varscan2
- PUS3 | c.596dup p.R201Sfs*3 | Frame Shift Ins (INS) | VAF 66/259 reads (25%) | catalogued as rs1171176058; called by mutect2, varscan2
- QRFPR | c.428G>A p.R143K | Missense Mutation (SNP) | VAF 58/259 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV100543715; called by muse, mutect2, varscan2
- RABGAP1 | c.2789del p.N930Tfs*15 | Frame Shift Del (DEL) | VAF 28/90 reads (31%) | catalogued as rs749213218, COSV101017169; called by mutect2, varscan2
- RABGGTA | c.213G>T p.E71D | Missense Mutation (SNP) | VAF 65/242 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.601); catalogued as rs1246531248; called by muse, mutect2, varscan2
- RAD23A | c.476C>T p.T159M | Missense Mutation (SNP) | VAF 34/125 reads (27%) | SIFT tolerated (0.37); PolyPhen benign (0.317); catalogued as rs150788485; called by muse, mutect2, varscan2
- RAI14 | c.816dup p.R273Tfs*15 | Frame Shift Ins (INS) | VAF 10/49 reads (20%) | catalogued as rs1355946206; called by mutect2, varscan2
- RANGAP1 | c.241C>T p.R81C | Missense Mutation (SNP) | VAF 36/144 reads (25%) | SIFT tolerated (0.13); PolyPhen benign (0.022); catalogued as rs1305287818; called by muse, mutect2, varscan2
- RASA1 | c.1776+1G>A p.X592_splice | Splice Site (SNP) | VAF 27/121 reads (22%) | catalogued as COSV57192684; called by muse, mutect2, varscan2
- RASAL2 | c.3016C>T p.R1006* | Nonsense Mutation (SNP) | VAF 21/90 reads (23%) | catalogued as rs1489934819; called by muse, mutect2, varscan2
- RASSF7 | c.613G>A p.A205T | Missense Mutation (SNP) | VAF 80/304 reads (26%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.679); catalogued as rs753186422; called by muse, mutect2, varscan2
- RBBP6 | c.1936C>T p.R646* | Nonsense Mutation (SNP) | VAF 16/67 reads (24%) | catalogued as rs1344347726, COSV60503845; called by muse, mutect2, varscan2
- RBM47 | c.1685C>T p.A562V (on ENST00000295971 / NM_001098634.2; = p.A493V on NM_019027.4) | Missense Mutation (SNP) | VAF 73/301 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); catalogued as rs780001417, COSV55930979; called by muse, varscan2
- RGS4 | c.611G>A p.C204Y | Missense Mutation (SNP) | VAF 66/306 reads (22%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.003); catalogued as rs1238116336; called by muse, mutect2, varscan2
- RIMS1 | c.1796G>A p.R599H | Missense Mutation (SNP) | VAF 43/148 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as rs772096503, COSV99327331; called by muse, mutect2, varscan2
- RIOK2 | c.446C>T p.S149L | Missense Mutation (SNP) | VAF 6/104 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1232431978; called by muse, mutect2
- RNF220 | c.673C>T p.P225S | Missense Mutation (SNP) | VAF 10/172 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV100698283; called by muse, mutect2
- RNF31 | c.3155G>A p.R1052H | Missense Mutation (SNP) | VAF 52/165 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs758763901; called by muse, mutect2, varscan2
- ROBO1 | c.2265del p.F755Lfs*28 | Frame Shift Del (DEL) | VAF 60/159 reads (38%) | catalogued as rs1192824348; called by mutect2, varscan2
- ROR1 | c.2240G>A p.R747Q | Missense Mutation (SNP) | VAF 85/314 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.192); catalogued as rs1026892288, COSV64284126; called by muse, mutect2, varscan2
- RPL22 | c.44dup p.K16Efs*9 | Frame Shift Ins (INS) | VAF 24/118 reads (20%) | catalogued as rs759765382; called by mutect2, varscan2
- RPL23 | c.225G>A p.K75= | Splice Region (SNP) | VAF 27/93 reads (29%) | catalogued as rs1320682678; called by muse, mutect2, varscan2
- RPLP0 | c.764C>T p.T255M | Missense Mutation (SNP) | VAF 48/133 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs746342849; called by muse, mutect2, varscan2
- RRP1 | c.1069C>T p.R357W | Missense Mutation (SNP) | VAF 104/353 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.551); catalogued as rs200137494; called by muse, mutect2, varscan2
- RSF1 | c.3611G>A p.R1204Q | Missense Mutation (SNP) | VAF 21/60 reads (35%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as rs577791059; called by muse, mutect2, varscan2
- RSPH10B2 | c.761G>A p.R254Q | Missense Mutation (SNP) | VAF 16/93 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs776601860; called by muse, mutect2, varscan2
- RSPO4 | c.635G>A p.R212H | Missense Mutation (SNP) | VAF 95/373 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as rs765335066, COSV54083496; called by muse, mutect2, varscan2
- RTL1 | c.3673G>A p.V1225I | Missense Mutation (SNP) | VAF 58/216 reads (27%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.003); catalogued as rs375169836; called by muse, mutect2, varscan2
- RTN4RL1 | c.229G>A p.A77T | Missense Mutation (SNP) | VAF 67/264 reads (25%) | SIFT tolerated (0.42); PolyPhen benign (0.041); catalogued as rs759023275, COSV100486505; called by muse, varscan2
- SAMD9 | c.3350C>T p.S1117F | Missense Mutation (SNP) | VAF 13/392 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV66072799; called by muse, mutect2
- SCRN1 | c.328A>G p.M110V | Missense Mutation (SNP) | VAF 24/86 reads (28%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as COSV54134375; called by muse, mutect2, varscan2
- SDC1 | c.830G>A p.R277H | Missense Mutation (SNP) | VAF 61/256 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs745498874, COSV54339097; called by muse, mutect2, varscan2
- SEC14L1 | c.1588G>A p.V530I | Missense Mutation (SNP) | VAF 30/136 reads (22%) | SIFT tolerated (0.25); PolyPhen benign (0.007); catalogued as rs774609620, COSV66723273; called by muse, mutect2, varscan2
- SEC24C | c.1375dup p.Q459Pfs*17 | Frame Shift Ins (INS) | VAF 46/174 reads (26%) | catalogued as rs764652839; called by mutect2, varscan2
- SEMA3D | c.1624G>A p.A542T | Missense Mutation (SNP) | VAF 36/135 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.027); catalogued as rs150477530; called by muse, mutect2, varscan2
- SEMA3G | c.2084G>A p.R695Q | Missense Mutation (SNP) | VAF 138/487 reads (28%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as rs779388206, COSV51594693; called by muse, mutect2, varscan2
- SEMA6B | c.1274A>G p.H425R | Missense Mutation (SNP) | VAF 61/218 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.786); catalogued as rs772782783; called by muse, mutect2, varscan2
- SEZ6L2 | c.1220G>A p.R407H (on ENST00000308713 / NM_001114099.3; = p.R337H on NM_012410.4) | Missense Mutation (SNP) | VAF 38/149 reads (26%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.862); catalogued as rs746757256, COSV58097024; called by muse, mutect2, varscan2
- SGSM1 | c.955C>T p.R319C | Missense Mutation (SNP) | VAF 63/242 reads (26%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.732); catalogued as rs367830127; called by muse, mutect2, varscan2
- SH3GL2 | c.1054C>A p.H352N | Missense Mutation (SNP) | VAF 23/206 reads (11%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV101013966; called by muse, mutect2, varscan2
- SIDT1 | c.1801G>A p.A601T | Missense Mutation (SNP) | VAF 28/125 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as rs772935487, COSV53498863; called by muse, mutect2, varscan2
- SIGLEC1 | c.1952del p.G651Vfs*13 | Frame Shift Del (DEL) | VAF 64/241 reads (27%) | catalogued as rs777478941; called by mutect2, pindel, varscan2
- SLC15A3 | c.1640G>T p.G547V | Missense Mutation (SNP) | VAF 39/279 reads (14%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.532); catalogued as COSV50006570; called by muse, mutect2, varscan2
- SLC16A7 | c.1126G>A p.G376R | Missense Mutation (SNP) | VAF 43/196 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs201299892, COSV99676986; called by muse, mutect2, varscan2
- SLC22A14 | c.305G>A p.W102* | Nonsense Mutation (SNP) | VAF 90/319 reads (28%) | catalogued as rs1259789496; called by muse, mutect2, varscan2
- SLC22A23 | c.1616C>T p.A539V | Missense Mutation (SNP) | VAF 64/263 reads (24%) | SIFT tolerated (0.5); PolyPhen benign (0.179); catalogued as rs371116667; called by muse, mutect2, varscan2
- SLC32A1 | c.869G>A p.R290H | Missense Mutation (SNP) | VAF 174/628 reads (28%) | SIFT tolerated (0.43); PolyPhen benign (0.07); catalogued as rs763883310; called by muse, mutect2, varscan2
- SLC38A1 | c.301A>G p.I101V | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT tolerated (0.21); PolyPhen benign (0.345); catalogued as rs373482105; called by muse, varscan2
- SLC38A1 | c.247G>A p.A83T | Missense Mutation (SNP) | VAF 20/83 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.35); catalogued as rs1387383265, COSV67064073; called by muse, varscan2
- SLC40A1 | c.39C>A p.C13* | Nonsense Mutation (SNP) | VAF 12/297 reads (4%) | catalogued as COSV53722916; called by muse, mutect2
- SLC6A13 | c.1441G>A p.E481K | Missense Mutation (SNP) | VAF 32/122 reads (26%) | SIFT tolerated (0.23); PolyPhen benign (0.334); catalogued as rs142374546; called by muse, mutect2, varscan2
- SLC6A15 | c.1346C>T p.A449V | Missense Mutation (SNP) | VAF 23/96 reads (24%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.924); catalogued as rs766602334; called by muse, mutect2, varscan2
- SLC6A15 | c.424G>A p.G142R | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs759281023; called by muse, mutect2, varscan2
- SLC9A1 | c.354T>C p.G118= | Splice Region (SNP) | VAF 51/194 reads (26%) | catalogued as COSV99849898; called by muse, mutect2, varscan2
- SLC9A4 | c.2364C>G p.H788Q | Missense Mutation (SNP) | VAF 44/196 reads (22%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0); catalogued as rs764264654; called by muse, mutect2, varscan2
- SLC9A5 | c.733G>T p.A245S | Missense Mutation (SNP) | VAF 132/493 reads (27%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.859); catalogued as COSV55360853; called by muse, mutect2, varscan2
- SLITRK5 | c.2285A>G p.N762S | Missense Mutation (SNP) | VAF 9/120 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.804); catalogued as COSV100280328, COSV100281069, COSV61522559; called by muse, mutect2
- SMAD4 | c.1322G>A p.R441H | Missense Mutation (SNP) | VAF 52/144 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.015); catalogued as COSV61685109, COSV61697913; called by muse, mutect2, varscan2
- SMARCA4 | c.4914C>T p.D1638= | Splice Region (SNP) | VAF 65/296 reads (22%) | catalogued as rs1555797441; ClinVar: likely benign; called by muse, varscan2
- SMARCB1 | c.644G>A p.R215H (on ENST00000263121; = p.R261H on NM_003073.5) | Missense Mutation (SNP) | VAF 134/470 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); catalogued as rs779587990, COSV54101534; called by muse, mutect2, varscan2
- SMG7 | c.3224G>T p.S1075I | Missense Mutation (SNP) | VAF 13/77 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.08); catalogued as COSV100750162; called by muse, mutect2, varscan2
- SMUG1 | c.664C>T p.R222* | Nonsense Mutation (SNP) | VAF 27/204 reads (13%) | catalogued as rs766141046, COSV99679308; called by muse, mutect2, varscan2
- SMURF2 | c.725T>C p.M242T | Missense Mutation (SNP) | VAF 40/212 reads (19%) | SIFT tolerated (0.64); PolyPhen benign (0.001); catalogued as COSV99300334; called by muse, mutect2, varscan2
- SMYD2 | c.1198G>A p.A400T | Missense Mutation (SNP) | VAF 56/227 reads (25%) | SIFT tolerated (0.31); PolyPhen benign (0.061); catalogued as rs752121860; called by muse, mutect2, varscan2
- SNAP29 | c.110C>G p.A37G | Missense Mutation (SNP) | VAF 53/263 reads (20%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV53143376; called by muse, mutect2, varscan2
- SNCAIP | c.1228G>A p.A410T | Missense Mutation (SNP) | VAF 48/197 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV54407815; called by muse, mutect2, varscan2
- SND1 | c.2584A>G p.M862V | Missense Mutation (SNP) | VAF 52/237 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.057); catalogued as COSV61236617; called by muse, mutect2, varscan2
- SNED1 | c.298G>A p.V100M | Missense Mutation (SNP) | VAF 88/344 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs200071415; called by muse, mutect2, varscan2
- SNTG2 | c.643C>T p.R215C | Missense Mutation (SNP) | VAF 19/106 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.763); catalogued as rs1033198912, COSV57984995; called by muse, mutect2, varscan2
- SNX21 | c.95C>T p.A32V | Missense Mutation (SNP) | VAF 28/143 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV61132444; called by muse, mutect2, varscan2
- SNX27 | c.265dup p.A89Gfs*22 | Frame Shift Ins (INS) | VAF 12/42 reads (29%) | catalogued as rs781657502; called by mutect2, varscan2
- SORL1 | c.4741del p.M1581Cfs*34 | Frame Shift Del (DEL) | VAF 38/151 reads (25%) | catalogued as rs1278336874; called by mutect2, pindel, varscan2
- SPATA31A6 | c.2801G>A p.S934N | Missense Mutation (SNP) | VAF 56/261 reads (21%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.861); catalogued as rs1160843357; called by muse, mutect2, varscan2
- SPINT1 | c.92A>G p.Q31R | Missense Mutation (SNP) | VAF 38/197 reads (19%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs758550828; called by muse, mutect2, varscan2
- SPPL2B | c.461G>A p.R154H | Missense Mutation (SNP) | VAF 28/131 reads (21%) | SIFT tolerated (0.66); PolyPhen possibly damaging (0.714); catalogued as rs754834119; called by muse, mutect2, varscan2
- SPRTN | c.1263dup p.I422Yfs*11 | Frame Shift Ins (INS) | VAF 33/120 reads (28%) | catalogued as rs567805129; called by mutect2, varscan2
- SPTAN1 | c.6389G>A p.R2130H | Missense Mutation (SNP) | VAF 110/467 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as rs373259652, COSV100823322; called by muse, mutect2, varscan2
- SRCAP | c.9182G>A p.R3061H | Missense Mutation (SNP) | VAF 64/232 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.038); catalogued as rs771914818, COSV52676156; called by muse, mutect2, varscan2
- SRCIN1 | c.1640C>T p.S547L (on ENST00000621492; = p.S513L on NM_025248.3) | Missense Mutation (SNP) | VAF 50/172 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.975); catalogued as rs1369031785; called by muse, mutect2, varscan2
- SRGAP1 | c.1012A>G p.M338V | Missense Mutation (SNP) | VAF 40/141 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.044); catalogued as COSV100755313; called by muse, mutect2, varscan2
- ST6GALNAC5 | c.434C>T p.A145V | Missense Mutation (SNP) | VAF 62/220 reads (28%) | PolyPhen probably damaging (1); catalogued as rs775136891, COSV59563539; called by mutect2, varscan2
- STAT2 | c.1467dup p.K490Qfs*41 | Frame Shift Ins (INS) | VAF 30/178 reads (17%) | catalogued as rs763294380; called by mutect2, varscan2
- STK36 | c.359G>A p.R120H | Missense Mutation (SNP) | VAF 34/130 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs770755293, COSV55305910; called by muse, varscan2
- SULF2 | c.526C>T p.R176W | Missense Mutation (SNP) | VAF 50/183 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as rs1307958275, COSV63417768; called by muse, mutect2, varscan2
- SYNJ2 | c.2149dup p.S717Ffs*3 | Frame Shift Ins (INS) | VAF 19/86 reads (22%) | catalogued as rs1437082431; called by mutect2, pindel, varscan2
- SZT2 | c.6430C>T p.R2144C (on ENST00000634258 / NM_001365999.1; = p.R2087C on NM_015284.4) | Missense Mutation (SNP) | VAF 104/364 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.293); catalogued as rs779827650, COSV100986956, COSV65171821; called by muse, mutect2, varscan2
- TAF11 | c.622dup p.I208Nfs*26 | Frame Shift Ins (INS) | VAF 36/123 reads (29%) | catalogued as rs1385487890; called by mutect2, varscan2
- TAF1L | c.3754C>T p.R1252W | Missense Mutation (SNP) | VAF 76/352 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54259076; called by muse, mutect2, varscan2
- TAF6L | c.127C>T p.R43C | Missense Mutation (SNP) | VAF 38/145 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1284882457; called by muse, mutect2, varscan2
- TATDN2 | c.1069G>A p.V357I | Missense Mutation (SNP) | VAF 46/216 reads (21%) | SIFT tolerated (0.38); PolyPhen benign (0.015); catalogued as rs372749908; called by muse, mutect2
- TBK1 | c.1286C>T p.A429V | Missense Mutation (SNP) | VAF 22/78 reads (28%) | SIFT tolerated (0.16); PolyPhen benign (0.24); catalogued as COSV100538174; called by muse, mutect2, varscan2
- TBP | c.623G>A p.R208Q | Missense Mutation (SNP) | VAF 29/116 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as COSV100027266, COSV57833376; called by muse, mutect2, varscan2
- TCF20 | c.5826del p.L1943Cfs*118 | Frame Shift Del (DEL) | VAF 24/98 reads (24%) | catalogued as rs756457255; called by mutect2, varscan2
- TCF3 | c.1573del p.R525Gfs*76 | Frame Shift Del (DEL) | VAF 36/120 reads (30%) | catalogued as COSV53646783, COSV53650404; called by mutect2, pindel, varscan2
- TCOF1 | c.77C>T p.A26V | Missense Mutation (SNP) | VAF 63/214 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as CM086971; called by muse, mutect2, varscan2
- TDRD6 | c.4558del p.M1520* | Frame Shift Del (DEL) | VAF 25/134 reads (19%) | catalogued as rs145334816, COSV60176047; called by mutect2, varscan2
- TEAD3 | c.254G>A p.R85Q | Missense Mutation (SNP) | VAF 46/216 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.906); catalogued as COSV58815985; called by muse, mutect2, varscan2
- TERT | c.1004C>T p.S335L | Missense Mutation (SNP) | VAF 27/816 reads (3%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as CD1512430; called by muse, mutect2
- TEX2 | c.587C>T p.S196L | Missense Mutation (SNP) | VAF 66/260 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs868977631, COSV51978393, COSV51984317; called by muse, mutect2, varscan2
- TFAP2C | c.991G>A p.A331T | Missense Mutation (SNP) | VAF 26/87 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV99571819; called by muse, mutect2, varscan2
- TFDP1 | c.122C>T p.P41L | Missense Mutation (SNP) | VAF 46/174 reads (26%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs140523394; called by muse, mutect2, varscan2
- TGIF2LX | c.158G>A p.R53H | Missense Mutation (SNP) | VAF 101/217 reads (47%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as COSV99383603; called by muse, mutect2, varscan2
- THBS3 | c.109C>T p.R37W | Missense Mutation (SNP) | VAF 110/395 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as rs1428877193, COSV57425618; called by muse, varscan2
- THEMIS2 | c.1060G>A p.D354N | Missense Mutation (SNP) | VAF 24/167 reads (14%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.862); catalogued as COSV61077162; called by muse, mutect2, varscan2
- THEMIS2 | c.1652dup p.P552Tfs*5 | Frame Shift Ins (INS) | VAF 64/262 reads (24%) | catalogued as rs750840849; called by mutect2, varscan2
- TIAM2 | c.2083C>T p.R695C | Missense Mutation (SNP) | VAF 30/109 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs150375770, COSV59688720; called by muse, mutect2, varscan2
- TLN2 | c.6116C>T p.A2039V | Missense Mutation (SNP) | VAF 58/222 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.152); catalogued as rs757423554, COSV60885669; called by muse, mutect2, varscan2
- TLR9 | c.2314G>A p.D772N | Missense Mutation (SNP) | VAF 54/176 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.127); catalogued as COSV62345616; called by muse, mutect2, varscan2
- TMC4 | c.1031T>C p.V344A (on ENST00000617472 / NM_001145303.3; = p.V338A on NM_144686.4) | Missense Mutation (SNP) | VAF 49/204 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.037); catalogued as rs565366367; called by muse, mutect2, varscan2
- TMC8 | c.559G>T p.G187C | Missense Mutation (SNP) | VAF 138/493 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs768942830; called by muse, mutect2, varscan2
- TMEM181 | c.1144C>T p.R382W | Missense Mutation (SNP) | VAF 55/235 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs771903296, COSV65564297; called by muse, mutect2, varscan2
- TNIK | c.3133C>T p.R1045* | Nonsense Mutation (SNP) | VAF 33/103 reads (32%) | catalogued as rs759338285, COSV52673190; called by muse, mutect2, varscan2
- TNIP2 | c.415G>A p.A139T | Missense Mutation (SNP) | VAF 80/291 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.019); catalogued as rs545493843, COSV59570339; called by muse, mutect2, varscan2
- TNRC6B | c.3356G>A p.R1119H (on ENST00000454349 / NM_001162501.2; = p.R1066H on NM_015088.3) | Missense Mutation (SNP) | VAF 33/101 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as rs192239190, COSV57301400; called by muse, mutect2, varscan2
- TNRC6C | c.5021C>T p.T1674M | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.745); catalogued as rs760172112; called by mutect2, varscan2
- TNS3 | c.1810G>A p.A604T | Missense Mutation (SNP) | VAF 46/193 reads (24%) | SIFT tolerated (0.49); PolyPhen benign (0.001); catalogued as rs561389270, COSV60793601; called by muse, mutect2, varscan2
- TNXB | c.7283C>T p.T2428M (on ENST00000647633; = p.T2181M on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/124 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs768556892; called by muse, mutect2, varscan2
- TOMM40 | c.112C>T p.P38S | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.992); catalogued as rs1490732654; called by muse, mutect2, varscan2
- TP53BP1 | c.2130del p.E711Nfs*12 | Frame Shift Del (DEL) | VAF 11/62 reads (18%) | catalogued as rs1375740992, COSV55498775; called by mutect2, pindel, varscan2
- TPO | c.1367G>T p.R456M | Missense Mutation (SNP) | VAF 81/336 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV61112529; called by muse, mutect2, varscan2
- TRMT6 | c.458del p.K153Nfs*9 | Frame Shift Del (DEL) | VAF 6/40 reads (15%) | catalogued as rs780358338; called by mutect2, varscan2
- TRPC7 | c.1610A>G p.Q537R | Missense Mutation (SNP) | VAF 30/136 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.688); catalogued as rs1176773246; called by muse, mutect2, varscan2
- TRPS1 | c.2083C>T p.R695C (on ENST00000220888 / NM_001330599.2; = p.R708C on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 76/290 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs1382648999, COSV55263859; called by mutect2, varscan2
- TSKS | c.704C>T p.T235M | Missense Mutation (SNP) | VAF 62/226 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.742); catalogued as COSV99883846; called by mutect2, varscan2
- TTBK2 | c.1949C>T p.A650V | Missense Mutation (SNP) | VAF 59/213 reads (28%) | SIFT tolerated, low confidence (0.93); PolyPhen benign (0); catalogued as rs369045579; ClinVar: benign; called by muse, mutect2, varscan2
- TTC6 | c.445G>A p.V149M | Missense Mutation (SNP) | VAF 33/209 reads (16%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.568); catalogued as rs1025422697; called by muse, mutect2, varscan2
- TXNDC9 | c.538G>A p.G180S | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT tolerated (0.12); PolyPhen benign (0.014); catalogued as rs954245673; called by muse, mutect2, varscan2
- TYRO3 | c.2450G>A p.G817D | Missense Mutation (SNP) | VAF 79/348 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs774952702, COSV55482036; called by muse, mutect2, varscan2
- UGT1A1 | c.1208G>A p.R403H | Missense Mutation (SNP) | VAF 54/299 reads (18%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.868); catalogued as rs140613392; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- UNC13B | c.1993C>T p.R665C | Missense Mutation (SNP) | VAF 41/145 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs774827252, COSV65931868; called by muse, mutect2, varscan2
- UNC13C | c.17dup p.K7Qfs*10 | Frame Shift Ins (INS) | VAF 28/87 reads (32%) | catalogued as rs1340319567; called by mutect2, pindel, varscan2
- UNC5A | c.2308C>T p.P770S | Missense Mutation (SNP) | VAF 24/140 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.914); catalogued as rs761665237; called by muse, mutect2, varscan2
- USHBP1 | c.1972C>T p.R658C | Missense Mutation (SNP) | VAF 38/157 reads (24%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as rs957553367, COSV52243999; called by muse, mutect2, varscan2
- USP35 | c.625G>A p.A209T | Missense Mutation (SNP) | VAF 40/131 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs755923450; called by muse, mutect2, varscan2
- USP35 | c.1059del p.M354Wfs*119 | Frame Shift Del (DEL) | VAF 48/170 reads (28%) | catalogued as rs761345427; called by mutect2, pindel, varscan2
- USP38 | c.3029G>A p.R1010Q | Missense Mutation (SNP) | VAF 16/82 reads (20%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.979); catalogued as rs374019822; called by muse, mutect2, varscan2
- USP9X | c.461G>A p.R154H | Missense Mutation (SNP) | VAF 54/95 reads (57%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.855); catalogued as rs367760990; called by muse, mutect2, varscan2
- USP9Y | c.363dup p.R122Sfs*10 | Frame Shift Ins (INS) | VAF 40/92 reads (43%) | catalogued as rs755153965; called by mutect2, varscan2
- VARS2 | c.2458G>A p.V820I | Missense Mutation (SNP) | VAF 35/147 reads (24%) | SIFT tolerated (0.15); PolyPhen benign (0.045); catalogued as rs754570639; called by muse, mutect2, varscan2
- VASN | c.727C>T p.R243C | Missense Mutation (SNP) | VAF 58/193 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs746792747; called by muse, mutect2, varscan2
- WASHC5 | c.2017-1G>A p.X673_splice | Splice Site (SNP) | VAF 46/214 reads (21%) | catalogued as rs1474507540; called by mutect2, varscan2
- WDR47 | c.241del p.R81Gfs*7 | Frame Shift Del (DEL) | VAF 17/70 reads (24%) | catalogued as rs1557951659, COSV63058584; called by mutect2, pindel, varscan2
- WDR59 | c.565G>A p.A189T | Missense Mutation (SNP) | VAF 26/85 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs754376026; called by muse, mutect2, varscan2
- WHAMM | c.1932_1934dup p.P658dup | In Frame Ins (INS) | VAF 56/292 reads (19%) | catalogued as rs750551364; called by mutect2, varscan2
- WNT9A | c.235G>A p.A79T | Missense Mutation (SNP) | VAF 84/297 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as rs1419624790, COSV55293583, COSV55294207; called by muse, mutect2, varscan2
- WWP1 | c.1223C>T p.T408M | Missense Mutation (SNP) | VAF 24/104 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1371065516, COSV99616990; called by muse, mutect2, varscan2
- XIRP1 | c.2141G>A p.R714Q | Missense Mutation (SNP) | VAF 30/126 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.227); catalogued as rs375819449; called by muse, mutect2, varscan2
- XPNPEP3 | c.1063G>A p.A355T | Missense Mutation (SNP) | VAF 30/155 reads (19%) | SIFT tolerated (0.34); PolyPhen benign (0.26); catalogued as rs1305062445; called by muse, mutect2, varscan2
- YIF1A | c.391del p.R131Gfs*50 | Frame Shift Del (DEL) | VAF 57/212 reads (27%) | catalogued as rs761507279; called by mutect2, pindel, varscan2
- ZBTB4 | c.11del p.P4Lfs*4 | Frame Shift Del (DEL) | VAF 13/70 reads (19%) | catalogued as rs765991494; called by mutect2, varscan2
- ZC3H4 | c.2809G>A p.V937M | Missense Mutation (SNP) | VAF 50/197 reads (25%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.534); catalogued as rs368486156; called by muse, mutect2, varscan2
- ZFHX2 | c.5407dup p.Q1803Pfs*33 | Frame Shift Ins (INS) | VAF 28/118 reads (24%) | catalogued as rs769243888; called by mutect2, varscan2
- ZFP36L2 | c.478C>T p.R160W | Missense Mutation (SNP) | VAF 96/383 reads (25%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); catalogued as rs1183688047; called by muse, varscan2
- ZIC1 | c.461C>T p.A154V | Missense Mutation (SNP) | VAF 135/404 reads (33%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.836); catalogued as COSV99291477, COSV99292620; called by muse, mutect2, varscan2
- ZKSCAN5 | c.2072dup p.N691Kfs*5 | Frame Shift Ins (INS) | VAF 92/352 reads (26%) | catalogued as rs556762260; called by mutect2, varscan2
- ZNF235 | c.338C>T p.A113V | Missense Mutation (SNP) | VAF 35/104 reads (34%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs370456639; called by muse, mutect2, varscan2
- ZNF248 | c.1282C>T p.R428* | Nonsense Mutation (SNP) | VAF 79/290 reads (27%) | catalogued as rs758962144; called by muse, mutect2, varscan2
- ZNF282 | c.910C>T p.R304W | Missense Mutation (SNP) | VAF 31/113 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.638); catalogued as rs1220675786, COSV100021413; called by muse, mutect2, varscan2
- ZNF318 | c.493C>T p.R165* | Nonsense Mutation (SNP) | VAF 36/152 reads (24%) | catalogued as rs751687081, COSV58592341; called by muse, mutect2, varscan2
- ZNF335 | c.1016G>A p.R339H | Missense Mutation (SNP) | VAF 56/189 reads (30%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.68); catalogued as rs202054542; called by muse, mutect2, varscan2
- ZNF423 | c.496C>T p.Q166* (on ENST00000563137 / NM_001379286.1; = p.Q158* on NM_015069.4) | Nonsense Mutation (SNP) | VAF 90/307 reads (29%) | catalogued as rs1555516098; called by muse, mutect2, varscan2
- ZNF469 | c.11666C>T p.A3889V (on ENST00000437464; = p.A3917V on NM_001367624.2) | Missense Mutation (SNP) | VAF 58/204 reads (28%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.469); catalogued as rs1161515745, COSV101458671; called by muse, mutect2, varscan2
- ZNF528 | c.1424G>T p.R475M | Missense Mutation (SNP) | VAF 44/206 reads (21%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.956); catalogued as COSV64618485; called by mutect2, varscan2
- ZNF540 | c.843del p.F281Lfs*4 | Frame Shift Del (DEL) | VAF 39/175 reads (22%) | catalogued as rs757107073, COSV57110076; called by mutect2, pindel, varscan2
- ZNF570 | c.1516dup p.T506Nfs*37 | Frame Shift Ins (INS) | VAF 23/102 reads (23%) | catalogued as rs1203012118; called by mutect2, varscan2
- ZNF628 | c.716C>T p.P239L | Missense Mutation (SNP) | VAF 43/122 reads (35%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs770382838; called by muse, mutect2, varscan2
- ZNF844 | c.767A>G p.K256R | Missense Mutation (SNP) | VAF 55/192 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.686); catalogued as rs1389699756, COSV101462785; called by muse, mutect2, varscan2
- ZNF880 | c.1611del p.K537Nfs*60 | Frame Shift Del (DEL) | VAF 59/273 reads (22%) | catalogued as rs759348115; called by mutect2, pindel, varscan2
- ZNF90 | c.345del p.G116Vfs*22 | Frame Shift Del (DEL) | VAF 28/131 reads (21%) | catalogued as rs781940988, COSV101367486; called by mutect2, pindel, varscan2
- ZNHIT1 | c.88C>T p.R30W | Missense Mutation (SNP) | VAF 39/163 reads (24%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.825); catalogued as rs779713104, COSV56184269; called by muse, mutect2, varscan2
- ZP1 | c.263C>T p.P88L | Missense Mutation (SNP) | VAF 37/178 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.036); catalogued as rs1001775590; called by muse, varscan2
- ZSCAN5B | c.403G>A p.G135S | Missense Mutation (SNP) | VAF 46/180 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.031); catalogued as rs752770185; called by muse, mutect2, varscan2
- ABCA5 | c.1301T>C p.F434S | Missense Mutation (SNP) | VAF 21/72 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ABCB4 | c.91del p.R31Gfs*7 | Frame Shift Del (DEL) | VAF 43/149 reads (29%) | called by mutect2, varscan2
- ABCC9 | c.3362G>A p.C1121Y | Missense Mutation (SNP) | VAF 71/273 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.319); called by muse, mutect2, varscan2
- ABCF2 | c.533G>T p.R178L | Missense Mutation (SNP) | VAF 35/138 reads (25%) | SIFT tolerated (0.21); PolyPhen benign (0.157); called by muse, mutect2, varscan2
- ACAP1 | c.2057C>T p.A686V | Missense Mutation (SNP) | VAF 43/157 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ACOXL | c.1450_1451dup p.H485Lfs*6 (on ENST00000389811 / NM_001371254.1; = p.H455Lfs*6 on NM_001142807.4) | Frame Shift Ins (INS) | VAF 38/172 reads (22%) | called by mutect2, varscan2
- ACR | c.1064del p.P355Hfs*38 | Frame Shift Del (DEL) | VAF 18/69 reads (26%) | called by mutect2, pindel
- ACTL10 | c.472C>T p.R158C | Missense Mutation (SNP) | VAF 12/194 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.571); called by muse, mutect2
- ADAM23 | c.1879T>C p.Y627H | Missense Mutation (SNP) | VAF 21/79 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ADAMTS14 | c.2987G>A p.R996K | Missense Mutation (SNP) | VAF 49/211 reads (23%) | SIFT tolerated (0.29); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- ADAMTS20 | c.4263G>A p.W1421* | Nonsense Mutation (SNP) | VAF 14/52 reads (27%) | called by muse, mutect2, varscan2
- ADGRF4 | c.1940dup p.I648Hfs*31 | Frame Shift Ins (INS) | VAF 9/97 reads (9%) | called by pindel, varscan2
- ADGRL2 | c.581del p.N194Ifs*14 | Frame Shift Del (DEL) | VAF 38/208 reads (18%) | called by mutect2, varscan2
- AFF4 | c.2121G>T p.E707D | Missense Mutation (SNP) | VAF 49/206 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- AGK | c.248dup p.N83Kfs*17 | Frame Shift Ins (INS) | VAF 13/58 reads (22%) | called by mutect2, varscan2
- AK9 | c.314dup p.E106Rfs*11 | Frame Shift Ins (INS) | VAF 18/82 reads (22%) | called by mutect2, pindel, varscan2
- AL031777.2 | c.157G>A p.A53T | Missense Mutation (SNP) | VAF 77/279 reads (28%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.077); called by mutect2, varscan2
- ALKBH5 | c.415T>C p.Y139H | Missense Mutation (SNP) | VAF 85/314 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ALX4 | c.743C>T p.A248V | Missense Mutation (SNP) | VAF 104/410 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- AMMECR1 | c.718A>G p.R240G | Missense Mutation (SNP) | VAF 32/73 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.26); called by muse, mutect2, varscan2
- ANAPC5 | c.2192A>G p.N731S | Missense Mutation (SNP) | VAF 12/353 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- ANK1 | c.3242del p.G1081Afs*3 | Frame Shift Del (DEL) | VAF 129/582 reads (22%) | called by mutect2, pindel, varscan2
- AOX1 | c.1347dup p.G450Wfs*8 | Frame Shift Ins (INS) | VAF 57/224 reads (25%) | called by mutect2, pindel, varscan2
- AP5Z1 | c.95T>C p.L32P | Missense Mutation (SNP) | VAF 48/186 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- APBB1 | c.111C>A p.N37K | Missense Mutation (SNP) | VAF 58/204 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.24); called by muse, mutect2, varscan2
- APBB2 | c.1527-2A>C p.X509_splice (on ENST00000295974 / NM_001166050.2; = p.X510_splice on NM_004307.2) | Splice Site (SNP) | VAF 61/169 reads (36%) | called by muse, mutect2, varscan2
- APC | c.2544dup p.D849Rfs*2 | Frame Shift Ins (INS) | VAF 83/394 reads (21%) | called by mutect2, pindel, varscan2
- APC2 | c.2066C>T p.A689V | Missense Mutation (SNP) | VAF 8/168 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); called by muse, mutect2
- APOA5 | c.671T>C p.L224P | Missense Mutation (SNP) | VAF 93/321 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- APOB | c.11165C>T p.P3722L | Missense Mutation (SNP) | VAF 38/273 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- APOB | c.10372A>G p.M3458V | Missense Mutation (SNP) | VAF 118/413 reads (29%) | SIFT tolerated (0.27); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- APTX | c.646G>A p.V216M | Missense Mutation (SNP) | VAF 121/408 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.593); called by muse, mutect2, varscan2
- ARAP3 | c.2699dup p.A901Rfs*18 | Frame Shift Ins (INS) | VAF 51/213 reads (24%) | called by mutect2, pindel, varscan2
- ARHGAP23 | c.3127G>A p.A1043T | Missense Mutation (SNP) | VAF 49/231 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); called by muse, mutect2, varscan2
- ARHGEF11 | c.3674A>G p.Q1225R | Missense Mutation (SNP) | VAF 34/162 reads (21%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0); called by muse, mutect2, varscan2
- ARL14EPL | c.364C>G p.P122A | Missense Mutation (SNP) | VAF 94/365 reads (26%) | SIFT tolerated (0.44); PolyPhen benign (0.271); called by muse, mutect2, varscan2
- ARRB1 | c.334G>A p.A112T | Missense Mutation (SNP) | VAF 39/182 reads (21%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- ARSI | c.1703G>T p.R568L | Missense Mutation (SNP) | VAF 27/120 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- ASTN1 | c.1380G>T p.M460I | Missense Mutation (SNP) | VAF 31/113 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ATP10D | c.335T>C p.V112A | Missense Mutation (SNP) | VAF 20/103 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.465); called by muse, mutect2, varscan2
- ATP10D | c.2573T>C p.L858P | Missense Mutation (SNP) | VAF 46/193 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ATP13A1 | c.1672A>G p.T558A | Missense Mutation (SNP) | VAF 36/144 reads (25%) | SIFT tolerated (0.35); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- ATP2A3 | c.391C>T p.R131C | Missense Mutation (SNP) | VAF 59/243 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- B4GALNT4 | c.1052T>C p.V351A | Missense Mutation (SNP) | VAF 61/466 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.098); called by muse, mutect2, varscan2
- BATF2 | c.40G>A p.D14N | Missense Mutation (SNP) | VAF 44/161 reads (27%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- BAZ2B | c.2906del p.K969Rfs*19 | Frame Shift Del (DEL) | VAF 23/107 reads (21%) | called by mutect2, pindel, varscan2
- BAZ2B | c.1717A>G p.N573D | Missense Mutation (SNP) | VAF 103/351 reads (29%) | SIFT tolerated (0.36); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- BOD1L1 | c.2889A>C p.K963N | Missense Mutation (SNP) | VAF 38/186 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.726); called by muse, mutect2, varscan2
- BRCA1 | c.299A>G p.E100G | Missense Mutation (SNP) | VAF 69/249 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0); called by muse, mutect2, varscan2
- BRD3 | c.298G>A p.E100K | Missense Mutation (SNP) | VAF 34/246 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- BRF2 | c.385C>T p.H129Y | Missense Mutation (SNP) | VAF 96/348 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.209); called by muse, mutect2, varscan2
- BSN | c.3133_3135dup p.E1045dup | In Frame Ins (INS) | VAF 24/104 reads (23%) | called by mutect2, varscan2
- BTNL8 | c.1103A>G p.Y368C | Missense Mutation (SNP) | VAF 100/309 reads (32%) | SIFT tolerated (0.18); PolyPhen benign (0.361); called by muse, mutect2, varscan2
- C18orf63 | c.1018del p.M340Cfs*6 | Frame Shift Del (DEL) | VAF 13/73 reads (18%) | called by mutect2, pindel, varscan2
- C1orf112 | c.8del p.L3Yfs*4 | Frame Shift Del (DEL) | VAF 14/66 reads (21%) | called by mutect2, pindel, varscan2
- C20orf194 | c.1610G>A p.G537D | Missense Mutation (SNP) | VAF 24/114 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- C5orf47 | c.65G>A p.G22D | Missense Mutation (SNP) | VAF 24/88 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); called by muse, mutect2, varscan2
- C6orf89 | c.675G>A p.W225* (on ENST00000373685; = p.W232* on NM_152734.4) | Nonsense Mutation (SNP) | VAF 49/203 reads (24%) | called by muse, mutect2, varscan2
- CACNB4 | c.502del p.R168Efs*39 | Frame Shift Del (DEL) | VAF 22/122 reads (18%) | called by mutect2, pindel, varscan2
- CACNG6 | c.725C>T p.T242I (on ENST00000252729 / NM_145814.1; = p.T171I on NM_031897.2) | Missense Mutation (SNP) | VAF 22/76 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.149); called by muse, mutect2, varscan2
- CAD | c.1567G>A p.A523T | Missense Mutation (SNP) | VAF 53/166 reads (32%) | SIFT tolerated (0.25); PolyPhen benign (0.171); called by muse, mutect2, varscan2
- CAGE1 | c.1841C>T p.A614V (on ENST00000512086; = p.A478V on NM_205864.3) | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT tolerated (0.36); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- CAPN2 | c.1154C>A p.P385H | Missense Mutation (SNP) | VAF 30/122 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CARMIL1 | c.3851A>G p.D1284G | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- CBLIF | c.724A>G p.K242E | Missense Mutation (SNP) | VAF 24/645 reads (4%) | SIFT tolerated (0.15); PolyPhen benign (0.014); called by muse, mutect2
- CCDC158 | c.491T>C p.M164T | Missense Mutation (SNP) | VAF 42/194 reads (22%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.946); called by muse, varscan2
- CCDC171 | c.3305A>T p.D1102V | Missense Mutation (SNP) | VAF 24/98 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CCND2 | c.616A>G p.S206G | Missense Mutation (SNP) | VAF 36/120 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.207); called by muse, mutect2, varscan2
- CCP110 | c.2777+11dup | Splice Region (INS) | VAF 14/70 reads (20%) | called by mutect2, pindel, varscan2
- CCT8L2 | c.1654del p.I552Sfs*4 | Frame Shift Del (DEL) | VAF 23/81 reads (28%) | called by mutect2, varscan2
- CD109 | c.3403T>C p.W1135R | Missense Mutation (SNP) | VAF 20/97 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.474); called by muse, mutect2, varscan2
- CD68 | c.356C>T p.A119V | Missense Mutation (SNP) | VAF 104/374 reads (28%) | SIFT tolerated (0.26); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CDC42BPG | c.1170C>A p.H390Q | Missense Mutation (SNP) | VAF 29/261 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CDH9 | c.1523C>T p.T508I | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.329); called by muse, mutect2, varscan2
- CEACAM1 | c.737A>C p.D246A | Missense Mutation (SNP) | VAF 71/253 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- CEL | c.1818del p.V607Cfs*100 (on ENST00000673714; = p.V604Cfs*100 on NM_001807.6) | Frame Shift Del (DEL) | VAF 12/49 reads (24%) | called by mutect2, varscan2
- CELF6 | c.128A>G p.H43R | Missense Mutation (SNP) | VAF 57/258 reads (22%) | SIFT tolerated (0.22); PolyPhen benign (0.402); called by muse, mutect2, varscan2
- CELSR1 | c.4108G>T p.D1370Y | Missense Mutation (SNP) | VAF 24/169 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- CFAP44 | c.3341T>C p.I1114T | Missense Mutation (SNP) | VAF 13/86 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- CFDP1 | c.386del p.P129Qfs*21 | Frame Shift Del (DEL) | VAF 27/140 reads (19%) | called by mutect2, pindel, varscan2
- CFP | c.305G>A p.R102Q | Missense Mutation (SNP) | VAF 131/261 reads (50%) | SIFT tolerated (0.07); PolyPhen benign (0.223); called by muse, mutect2, varscan2
- CHD6 | c.327G>T p.K109N | Missense Mutation (SNP) | VAF 67/169 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.761); called by muse, mutect2, varscan2
- CHML | c.832T>C p.C278R | Missense Mutation (SNP) | VAF 26/148 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CHORDC1 | c.965del p.K322Sfs*30 | Frame Shift Del (DEL) | VAF 19/103 reads (18%) | called by mutect2, pindel, varscan2
- CHRNA10 | c.1276A>C p.M426L | Missense Mutation (SNP) | VAF 27/112 reads (24%) | SIFT tolerated (0.26); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- CIAPIN1 | c.310G>A p.D104N | Missense Mutation (SNP) | VAF 16/99 reads (16%) | SIFT tolerated (0.48); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CLASP2 | c.1772A>G p.K591R | Missense Mutation (SNP) | VAF 26/102 reads (25%) | SIFT tolerated (0.66); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- CLCN3 | c.692T>C p.V231A | Missense Mutation (SNP) | VAF 19/104 reads (18%) | SIFT tolerated (0.46); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- CLDN2 | c.310T>C p.C104R | Missense Mutation (SNP) | VAF 166/264 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CLEC4E | c.86T>C p.I29T | Missense Mutation (SNP) | VAF 31/93 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0); called by muse, mutect2, varscan2
- CLEC9A | c.90A>G p.S30= | Splice Region (SNP) | VAF 12/95 reads (13%) | called by muse, varscan2
- CLIP2 | c.2992C>T p.R998W | Missense Mutation (SNP) | VAF 34/124 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CLSTN3 | c.2464C>T p.R822C | Missense Mutation (SNP) | VAF 34/132 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.39); called by muse, mutect2, varscan2
- CLTC | c.1558A>T p.N520Y | Missense Mutation (SNP) | VAF 30/113 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.176); called by muse, mutect2, varscan2
- CMPK1 | c.500dup p.S169Efs*2 | Frame Shift Ins (INS) | VAF 20/74 reads (27%) | called by mutect2, pindel, varscan2
- CMYA5 | c.8086C>T p.Q2696* | Nonsense Mutation (SNP) | VAF 53/183 reads (29%) | called by muse, mutect2, varscan2
- CNNM2 | c.1282G>A p.V428I | Missense Mutation (SNP) | VAF 24/584 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.572); called by muse, mutect2
- CNTRL | c.358A>G p.N120D | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- COBLL1 | c.580dup p.T194Nfs*23 (on ENST00000392717; = p.T156Nfs*23 on NM_014900.5) | Frame Shift Ins (INS) | VAF 24/132 reads (18%) | called by mutect2, pindel, varscan2
- COL12A1 | c.5266C>A p.P1756T | Missense Mutation (SNP) | VAF 21/83 reads (25%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.886); called by muse, mutect2, varscan2
- COL25A1 | c.1397A>G p.Q466R | Missense Mutation (SNP) | VAF 13/83 reads (16%) | SIFT tolerated (0.59); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- COL4A3 | c.4972dup p.I1658Nfs*39 | Frame Shift Ins (INS) | VAF 22/106 reads (21%) | called by mutect2, varscan2
- COLEC12 | c.1454G>A p.G485D | Missense Mutation (SNP) | VAF 22/141 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CPD | c.690dup p.A231Rfs*38 | Frame Shift Ins (INS) | VAF 13/55 reads (24%) | called by mutect2, pindel, varscan2
- CPEB4 | c.1579T>C p.S527P | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- CPO | c.86G>T p.R29I | Missense Mutation (SNP) | VAF 51/145 reads (35%) | SIFT tolerated (0.17); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- CRBN | c.1243del p.W415Gfs*3 | Frame Shift Del (DEL) | VAF 77/266 reads (29%) | called by mutect2, varscan2
- CSF1 | c.125T>C p.M42T | Missense Mutation (SNP) | VAF 29/118 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.237); called by muse, mutect2, varscan2
- CTNNBL1 | c.425C>T p.A142V | Missense Mutation (SNP) | VAF 67/243 reads (28%) | SIFT tolerated (0.13); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- CTSH | c.325T>C p.Y109H | Missense Mutation (SNP) | VAF 28/138 reads (20%) | SIFT tolerated (0.72); PolyPhen benign (0.001); called by muse, varscan2
- CTTNBP2 | c.1646dup p.P550Afs*31 | Frame Shift Ins (INS) | VAF 112/452 reads (25%) | called by mutect2, pindel, varscan2
- CUEDC1 | c.332dup p.E112Gfs*10 | Frame Shift Ins (INS) | VAF 43/143 reads (30%) | called by mutect2, pindel, varscan2
- CXXC5 | c.824G>A p.C275Y | Missense Mutation (SNP) | VAF 47/162 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DCAF4L2 | c.119C>T p.A40V | Missense Mutation (SNP) | VAF 42/314 reads (13%) | SIFT tolerated (0.42); PolyPhen benign (0); called by muse, mutect2, varscan2
- DCAF8 | c.1004A>G p.Y335C | Missense Mutation (SNP) | VAF 33/125 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DCHS1 | c.4967T>C p.V1656A | Missense Mutation (SNP) | VAF 124/487 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- DCLK1 | c.1430T>C p.I477T | Missense Mutation (SNP) | VAF 19/96 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DDIAS | c.2477del p.N826Ifs*2 | Frame Shift Del (DEL) | VAF 27/94 reads (29%) | called by mutect2, varscan2
- DDX53 | c.35A>G p.E12G | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.227); called by muse, mutect2, varscan2
- DIO1 | c.179A>G p.N60S | Missense Mutation (SNP) | VAF 18/416 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.012); called by muse, mutect2
- DMXL2 | c.7681del p.M2561Wfs*34 | Frame Shift Del (DEL) | VAF 46/208 reads (22%) | called by mutect2, pindel, varscan2
- DNAH1 | c.7594A>G p.T2532A | Missense Mutation (SNP) | VAF 13/316 reads (4%) | SIFT tolerated (0.62); PolyPhen benign (0.015); called by muse, mutect2
- DNAH10 | c.10976G>A p.R3659Q (on ENST00000409039; = p.R3598Q on NM_207437.3) | Missense Mutation (SNP) | VAF 110/450 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.342); called by muse, mutect2, varscan2
- DNAH11 | c.13240del p.T4414Qfs*72 | Frame Shift Del (DEL) | VAF 14/119 reads (12%) | called by mutect2, pindel, varscan2
- DNAH17 | c.5452C>T p.P1818S | Missense Mutation (SNP) | VAF 28/154 reads (18%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- DNAH3 | c.4015dup p.A1339Gfs*18 | Frame Shift Ins (INS) | VAF 15/83 reads (18%) | called by mutect2, pindel, varscan2
- DNAH5 | c.5563del p.I1855Sfs*16 | Frame Shift Del (DEL) | VAF 36/204 reads (18%) | called by mutect2, varscan2
- DNAJB6 | c.312dup p.G105Wfs*9 | Frame Shift Ins (INS) | VAF 20/139 reads (14%) | called by mutect2, pindel, varscan2
- DOCK7 | c.6226T>G p.L2076V (on ENST00000635253 / NM_001367561.1; = p.L2045V on NM_033407.3) | Missense Mutation (SNP) | VAF 31/202 reads (15%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- DOCK8 | c.4549A>T p.S1517C | Missense Mutation (SNP) | VAF 80/328 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DTX4 | c.1080del p.V361Sfs*6 | Frame Shift Del (DEL) | VAF 20/108 reads (19%) | called by mutect2, pindel, varscan2
- DUSP10 | c.742C>T p.P248S | Missense Mutation (SNP) | VAF 72/274 reads (26%) | SIFT tolerated (0.46); PolyPhen benign (0.011); called by muse, mutect2
- DYNC2I2 | c.698T>C p.V233A | Missense Mutation (SNP) | VAF 74/276 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- ECT2 | c.1362G>A p.W454* (on ENST00000392692 / NM_001349098.2; = p.W423* on NM_018098.6 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 11/79 reads (14%) | called by muse, mutect2, varscan2
- EDRF1 | c.2590G>T p.V864L (on ENST00000356792 / NM_001202438.2; = p.V830L on NM_015608.2) | Missense Mutation (SNP) | VAF 39/240 reads (16%) | SIFT tolerated (0.26); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- EEF1A2 | c.714del p.T239Rfs*40 | Frame Shift Del (DEL) | VAF 40/191 reads (21%) | called by mutect2, pindel, varscan2
- EID2 | c.394G>T p.G132* | Nonsense Mutation (SNP) | VAF 62/230 reads (27%) | called by muse, mutect2, varscan2
- EIF4A3 | c.479T>C p.V160A | Missense Mutation (SNP) | VAF 30/107 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.391); called by muse, varscan2
- ELOVL6 | c.604C>T p.Q202* | Nonsense Mutation (SNP) | VAF 106/416 reads (25%) | called by muse, mutect2, varscan2
- EN1 | c.386C>T p.A129V | Missense Mutation (SNP) | VAF 75/221 reads (34%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- EPHA7 | c.2995T>C p.*999Rext*31 | Nonstop Mutation (SNP) | VAF 39/160 reads (24%) | called by muse, mutect2, varscan2
- ERC2 | c.2060del p.K687Rfs*11 | Frame Shift Del (DEL) | VAF 17/86 reads (20%) | called by mutect2, pindel, varscan2
- ERCC4 | c.2742del p.K916Sfs*4 | Frame Shift Del (DEL) | VAF 67/252 reads (27%) | called by mutect2, pindel, varscan2
- ERVMER34-1 | c.813A>T p.K271N | Missense Mutation (SNP) | VAF 91/356 reads (26%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0.373); called by muse, mutect2, varscan2
- ESPL1 | c.3523G>T p.G1175C | Missense Mutation (SNP) | VAF 87/353 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- ESPN | c.211G>A p.A71T | Missense Mutation (SNP) | VAF 60/191 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.89); called by muse, mutect2, varscan2
1,027 further variants in this file (451 protein-altering or splice-affecting, 339 silent, 237 other) are not listed here.
